Somatic mutation profile of tumor specimen C3L-00781-04 (aliquot CPT0070260009) from CPTAC case C3L-00781, project CPTAC-3 (Uterus, NOS — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Uterus, NOS; AJCC pathologic stage: Stage II; FIGO stage: Stage II; Tumor grade: G3; Age at diagnosis: 48.6 years (17,739 days).
Specimen C3L-00781-04: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Uterus; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 58ef7ff8-68cb-4abd-9831-f05ea7ee1e62.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-00781-31 (Blood Derived Normal), aliquot CPT0071030002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ad51c26d-b41b-47e4-9b01-43152df8ab91

The open-access MAF lists 1,632 somatic variants for this specimen: 1,064 protein-altering or splice-affecting, 353 silent, 215 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 680, Silent 353, Frame Shift Del 256, Intron 117, Nonsense Mutation 53, 3'UTR 37, Frame Shift Ins 32, 5'UTR 21, Splice Site 17, RNA 17, 5'Flank 15, Splice Region 14.

Variants (750 of 1,632; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BSCL2 | c.412C>T p.R138* | Nonsense Mutation (SNP) | VAF 60/522 reads (11%) | catalogued as rs137852970, CM014524; ClinVar: pathogenic; called by muse, mutect2, varscan2
- CHD2 | c.522del p.V175* | Frame Shift Del (DEL) | VAF 40/154 reads (26%) | catalogued as rs748694853; ClinVar: likely pathogenic; called by mutect2, varscan2
- ERF | c.256C>T p.R86C | Missense Mutation (SNP) | VAF 38/122 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs587777008, CM135641; ClinVar: pathogenic; called by muse, mutect2
- IFT81 | c.259C>T p.R87C | Missense Mutation (SNP) | VAF 31/152 reads (20%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.998); catalogued as rs761469100, COSV54364586; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- KMT2A | c.2318del p.P773Rfs*8 | Frame Shift Del (DEL) | VAF 97/377 reads (26%) | catalogued as rs782297546; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- KMT2D | c.3704del p.G1235Vfs*95 | Frame Shift Del (DEL) | VAF 51/184 reads (28%) | catalogued as rs1364500207, COSV99979040; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- PIGO | c.2361del p.T788Lfs*25 | Frame Shift Del (DEL) | VAF 95/386 reads (25%) | catalogued as rs770591449, COSV99956719; ClinVar: likely pathogenic / pathogenic; called by mutect2, pindel, varscan2
- PIK3CA | c.323G>A p.R108H | Missense Mutation (SNP) | VAF 16/61 reads (26%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen probably damaging (0.98); catalogued as rs886042002, CM162636, COSV55873442, COSV55926654, COSV55949642; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PIK3R1 | c.1354T>C p.Y452H (on ENST00000521381 / NM_181523.3; = p.Y182H on NM_181504.4) | Missense Mutation (SNP) | VAF 32/114 reads (28%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen probably damaging (0.989); catalogued as COSV57129574, COSV57137992; called by muse, mutect2, varscan2
- PIK3R1 | c.1699A>G p.K567E (on ENST00000521381 / NM_181523.3; = p.K297E on NM_181504.4) | Missense Mutation (SNP) | VAF 48/170 reads (28%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as COSV57123609; called by muse, mutect2, varscan2
- PTEN | c.800del p.K267Rfs*9 | Frame Shift Del (DEL) | VAF 84/330 reads (25%) | catalogued as rs121913289; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- PTEN | c.1027-1G>T p.X343_splice | Splice Site (SNP) | VAF 130/490 reads (27%) | hotspot (GDC flag); catalogued as CS1413088, COSV64290834, COSV64293694, COSV64298429; called by muse, mutect2, varscan2
- TRPS1 | c.2693A>G p.N898S (on ENST00000220888 / NM_001330599.2; = p.N911S on NM_014112.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 151/591 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1554617580, CM154762; ClinVar: pathogenic; called by muse, mutect2, varscan2
- VWF | c.2435del p.P812Rfs*31 | Frame Shift Del (DEL) | VAF 69/221 reads (31%) | catalogued as rs62643632, CD920917, CM074633, COSV54614968; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- WDR62 | c.3921dup p.V1308Rfs*18 | Frame Shift Ins (INS) | VAF 33/135 reads (24%) | catalogued as rs587776900; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- AARS2 | c.1697C>T p.A566V | Missense Mutation (SNP) | VAF 13/375 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV55114196, COSV55116521; called by muse, mutect2
- ABCA7 | c.5879C>T p.A1960V | Missense Mutation (SNP) | VAF 24/76 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.131); catalogued as COSV99566819; called by muse, varscan2
- ABCB4 | c.355T>C p.Y119H | Missense Mutation (SNP) | VAF 70/291 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs999455532; called by muse, mutect2, varscan2
- ABCC10 | c.1465C>T p.R489W (on ENST00000372530 / NM_001198934.2; = p.R446W on NM_033450.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 38/150 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1472560845; called by muse, mutect2, varscan2
- ACAT2 | c.668G>A p.R223H | Missense Mutation (SNP) | VAF 48/190 reads (25%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as rs747254833; called by muse, mutect2, varscan2
- ACSS1 | c.1511C>T p.P504L | Missense Mutation (SNP) | VAF 34/116 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs774284268; called by muse, mutect2, varscan2
- ACSS1 | c.784del p.D262Ifs*56 | Frame Shift Del (DEL) | VAF 74/306 reads (24%) | catalogued as COSV100053351; called by mutect2, pindel, varscan2
- ACVR2A | c.1310del p.K437Rfs*5 | Frame Shift Del (DEL) | VAF 28/114 reads (25%) | catalogued as rs764719749, COSV104385546; called by mutect2, varscan2
- ADAM23 | c.391G>A p.V131I | Missense Mutation (SNP) | VAF 57/207 reads (28%) | SIFT tolerated (0.4); PolyPhen benign (0.013); catalogued as rs769762739, COSV52229295; called by muse, mutect2, varscan2
- ADAM8 | c.1274G>C p.G425A | Missense Mutation (SNP) | VAF 38/94 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV69864406; called by muse, mutect2, varscan2
- ADGRB1 | c.2908G>A p.V970M | Missense Mutation (SNP) | VAF 49/181 reads (27%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.923); catalogued as rs577805420, COSV60100189; called by muse, mutect2, varscan2
- ADGRF4 | c.245del p.K82Sfs*29 | Frame Shift Del (DEL) | VAF 56/219 reads (26%) | catalogued as rs764604854; called by mutect2, pindel, varscan2
- ADGRL2 | c.919G>A p.D307N | Missense Mutation (SNP) | VAF 135/507 reads (27%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as rs140256557, COSV54684028; called by muse, mutect2, varscan2
- ADH5 | c.118A>G p.I40V | Missense Mutation (SNP) | VAF 35/106 reads (33%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs757259145; called by muse, mutect2, varscan2
- ADORA2A | c.154G>A p.D52N | Missense Mutation (SNP) | VAF 89/287 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs199999926; called by muse, mutect2, varscan2
- AHDC1 | c.298C>T p.P100S | Missense Mutation (SNP) | VAF 39/143 reads (27%) | SIFT tolerated, low confidence (0.92); PolyPhen benign (0.412); catalogued as COSV55939797; called by muse, mutect2, varscan2
- AL645922.1 | c.230G>A p.R77Q | Missense Mutation (SNP) | VAF 113/360 reads (31%) | SIFT tolerated (0.26); PolyPhen benign (0.006); catalogued as rs779595202; called by muse, mutect2, varscan2
- ALDH1L2 | c.1714C>T p.R572C | Missense Mutation (SNP) | VAF 78/293 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs766129624; called by muse, mutect2, varscan2
- AMOTL2 | c.521C>T p.A174V | Missense Mutation (SNP) | VAF 50/146 reads (34%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as rs764129675; called by muse, mutect2, varscan2
- ANK1 | c.3511C>T p.R1171C | Missense Mutation (SNP) | VAF 57/230 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.014); catalogued as rs1428777679, COSV55888428; called by muse, mutect2, varscan2
- ANKRD11 | c.7783G>A p.D2595N | Missense Mutation (SNP) | VAF 152/537 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV56374803; called by muse, mutect2, varscan2
- ANKRD18B | c.1176del p.V393Wfs*11 | Frame Shift Del (DEL) | VAF 16/80 reads (20%) | catalogued as rs745540260; called by mutect2, pindel, varscan2
- ANKS1A | c.1342C>T p.R448W | Missense Mutation (SNP) | VAF 52/219 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.153); catalogued as rs778346305; called by muse, mutect2, varscan2
- AP2A1 | c.550C>T p.P184S | Missense Mutation (SNP) | VAF 51/202 reads (25%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.692); catalogued as rs1340433262; called by muse, mutect2, varscan2
- APBA3 | c.23G>A p.R8Q | Missense Mutation (SNP) | VAF 35/183 reads (19%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.001); catalogued as rs776734372; called by muse, mutect2, varscan2
- ARHGAP17 | c.2440del p.Q814Nfs*23 (on ENST00000289968 / NM_001006634.3; = p.Q736Nfs*23 on NM_018054.6) | Frame Shift Del (DEL) | VAF 62/233 reads (27%) | catalogued as rs773922861; called by mutect2, varscan2
- ARHGAP35 | c.2254A>G p.S752G | Missense Mutation (SNP) | VAF 54/161 reads (34%) | SIFT tolerated (0.18); PolyPhen benign (0.012); catalogued as rs545335379; called by muse, mutect2, varscan2
- ARHGAP44 | c.1934G>A p.R645Q | Missense Mutation (SNP) | VAF 22/59 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs1341564374; called by muse, mutect2, varscan2
- ARHGEF10L | c.1343G>A p.R448H | Missense Mutation (SNP) | VAF 34/156 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.954); catalogued as rs963682629, COSV51436523; called by muse, mutect2, varscan2
- ARHGEF19 | c.358C>T p.R120* | Nonsense Mutation (SNP) | VAF 43/159 reads (27%) | catalogued as rs748376278; called by muse, mutect2, varscan2
- ARID1A | c.1015del p.A339Lfs*24 | Frame Shift Del (DEL) | VAF 8/17 reads (47%) | catalogued as rs1232964733; called by mutect2, varscan2
- ARL15 | c.497G>A p.R166H | Missense Mutation (SNP) | VAF 49/276 reads (18%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.616); catalogued as rs369214411; called by muse, mutect2, varscan2
- ASIC3 | c.236G>A p.R79Q | Missense Mutation (SNP) | VAF 60/245 reads (24%) | SIFT tolerated (0.54); PolyPhen benign (0.084); catalogued as rs750604015; called by muse, mutect2, varscan2
- ATAD2B | c.4336-1G>T p.X1446_splice | Splice Site (SNP) | VAF 36/143 reads (25%) | catalogued as rs1292910734; called by muse, mutect2, varscan2
- ATG4D | c.659C>T p.A220V | Missense Mutation (SNP) | VAF 55/250 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.688); catalogued as rs774056462, COSV100520986; called by muse, mutect2, varscan2
- ATP6V1B2 | c.388C>T p.R130W | Missense Mutation (SNP) | VAF 47/189 reads (25%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.807); catalogued as rs1328244713; called by muse, mutect2, varscan2
- AURKB | c.856G>A p.V286I | Missense Mutation (SNP) | VAF 18/66 reads (27%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as rs764223601; called by muse, mutect2
- BABAM2 | c.392G>A p.R131H | Missense Mutation (SNP) | VAF 34/156 reads (22%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.703); catalogued as rs766228855; called by muse, mutect2, varscan2
- BEST2 | c.325G>A p.V109M | Missense Mutation (SNP) | VAF 26/87 reads (30%) | SIFT tolerated (0.17); PolyPhen benign (0.164); catalogued as rs769244875; called by muse, mutect2, varscan2
- BICRA | c.1384G>A p.A462T | Missense Mutation (SNP) | VAF 36/107 reads (34%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.9); catalogued as COSV101194317; called by muse, mutect2, varscan2
- BMP2 | c.325G>A p.V109M | Missense Mutation (SNP) | VAF 21/58 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.776); catalogued as rs1345011787; called by muse, mutect2, varscan2
- BMPR1A | c.1058A>G p.Q353R | Missense Mutation (SNP) | VAF 56/747 reads (7%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.954); catalogued as rs1405441693; ClinVar: uncertain significance; called by muse, mutect2
- BNIP5 | c.1702del p.Y568Tfs*12 | Frame Shift Del (DEL) | VAF 14/172 reads (8%) | catalogued as COSV71325486; called by mutect2, pindel
- BRAT1 | c.355G>A p.V119M | Missense Mutation (SNP) | VAF 23/117 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs756690295; called by muse, mutect2, varscan2
- BRWD1 | c.3166C>T p.R1056C | Missense Mutation (SNP) | VAF 27/131 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs766554156; called by muse, mutect2, varscan2
- BST1 | c.457G>A p.D153N | Missense Mutation (SNP) | VAF 46/116 reads (40%) | SIFT tolerated (0.58); PolyPhen probably damaging (0.995); catalogued as rs375412643; called by muse, mutect2, varscan2
- BTNL8 | c.572T>C p.V191A | Missense Mutation (SNP) | VAF 74/304 reads (24%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.525); catalogued as rs554947046; called by muse, mutect2, varscan2
- C17orf99 | c.778C>T p.R260C | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0); catalogued as rs770106906, COSV56745237; called by muse, mutect2, varscan2
- C1S | c.872-5T>C | Splice Region (SNP) | VAF 135/500 reads (27%) | catalogued as rs1555162247; called by muse, mutect2, varscan2
- C1S | c.1567C>T p.R523* | Nonsense Mutation (SNP) | VAF 92/449 reads (20%) | catalogued as rs781856506, CM016095; called by muse, mutect2, varscan2
- C5 | c.1579A>G p.N527D | Missense Mutation (SNP) | VAF 29/409 reads (7%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.828); catalogued as rs767594750; called by muse, mutect2
- C7 | c.1436C>T p.P479L | Missense Mutation (SNP) | VAF 19/65 reads (29%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.902); catalogued as rs747361977; called by muse, mutect2, varscan2
- C7orf26 | c.1208del p.P403Rfs*39 | Frame Shift Del (DEL) | VAF 46/209 reads (22%) | catalogued as COSV60418577; called by pindel, varscan2
- C8orf82 | c.412G>A p.V138M | Missense Mutation (SNP) | VAF 23/74 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.644); catalogued as rs753686174; called by muse, mutect2, varscan2
- CACNA1A | c.2809G>A p.V937M | Missense Mutation (SNP) | VAF 30/86 reads (35%) | SIFT tolerated (0.25); PolyPhen benign (0.121); catalogued as rs767187794, COSV64190238; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CACNA1C | c.5180C>T p.P1727L | Missense Mutation (SNP) | VAF 41/134 reads (31%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.988); catalogued as COSV59705706; called by muse, mutect2, varscan2
- CACNA1H | c.3082G>A p.D1028N | Missense Mutation (SNP) | VAF 65/229 reads (28%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.99); catalogued as rs745354512; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CACNB2 | c.930_931del p.H310Qfs*3 (on ENST00000324631 / NM_201596.3; = p.H255Qfs*3 on NM_000724.4) | Frame Shift Del (DEL) | VAF 100/433 reads (23%) | catalogued as rs1206445947; called by pindel, varscan2
- CAMSAP2 | c.4309del p.M1437* (on ENST00000236925 / NM_001297707.2; = p.M1426* on NM_203459.3) | Frame Shift Del (DEL) | VAF 64/278 reads (23%) | catalogued as rs1375954479; called by mutect2, pindel, varscan2
- CC2D1A | c.1720C>T p.R574W | Missense Mutation (SNP) | VAF 46/164 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.698); catalogued as rs527913042, COSV100528344; called by muse, mutect2, varscan2
- CCDC168 | c.6356del p.N2119Tfs*6 | Frame Shift Del (DEL) | VAF 50/156 reads (32%) | catalogued as rs1349277202; called by mutect2, varscan2
- CCDC175 | c.1148dup p.L383Ffs*8 | Frame Shift Ins (INS) | VAF 22/88 reads (25%) | catalogued as rs921476762; called by mutect2, pindel, varscan2
- CCDC47 | c.337_339del p.S114del | In Frame Del (DEL) | VAF 46/166 reads (28%) | catalogued as rs757511026; called by pindel, varscan2
- CCDC65 | c.1298G>A p.R433Q | Missense Mutation (SNP) | VAF 106/376 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.026); catalogued as rs766802543; called by muse, mutect2, varscan2
- CCDC89 | c.839T>C p.I280T | Missense Mutation (SNP) | VAF 69/281 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as rs1389121286, COSV57033931; called by muse, mutect2, varscan2
- CCER1 | c.124C>T p.R42C | Missense Mutation (SNP) | VAF 84/275 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as rs1242580134, COSV62647948; called by muse, mutect2, varscan2
- CD96 | c.25G>A p.A9T | Missense Mutation (SNP) | VAF 76/283 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.537); catalogued as rs771509782; called by muse, mutect2, varscan2
- CDC73 | c.1565T>C p.M522T | Missense Mutation (SNP) | VAF 42/194 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.569); catalogued as COSV100813885; called by muse, mutect2, varscan2
- CDH11 | c.998del p.K333Sfs*3 | Frame Shift Del (DEL) | VAF 9/47 reads (19%) | catalogued as rs1208977261; called by mutect2, pindel, varscan2
- CDHR5 | c.1973C>T p.S658L (on ENST00000358353 / NM_001171968.2; = p.S664L on NM_021924.5) | Missense Mutation (SNP) | VAF 47/153 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as rs761696569; called by muse, mutect2, varscan2
- CDHR5 | c.506C>T p.A169V | Missense Mutation (SNP) | VAF 48/165 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.058); catalogued as rs1235357313; called by muse, mutect2, varscan2
- CDK12 | c.3187T>C p.S1063P | Missense Mutation (SNP) | VAF 45/223 reads (20%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as COSV71002802; called by muse, mutect2, varscan2
- CDX2 | c.916del p.V306Cfs*2 | Frame Shift Del (DEL) | VAF 33/104 reads (32%) | catalogued as rs773511514; called by mutect2, pindel, varscan2
- CELSR3 | c.746C>A p.P249Q | Missense Mutation (SNP) | VAF 52/159 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.305); catalogued as COSV50874312, COSV50896306; called by muse, mutect2, varscan2
- CENPF | c.9239C>T p.P3080L | Missense Mutation (SNP) | VAF 86/340 reads (25%) | SIFT tolerated (0.21); PolyPhen benign (0.001); catalogued as rs775896085, COSV100871617; called by muse, mutect2, varscan2
- CENPJ | c.1136_1138del p.G379del | In Frame Del (DEL) | VAF 62/232 reads (27%) | catalogued as rs746114866; called by pindel, varscan2
- CEP170B | c.1933del p.Q645Rfs*179 (on ENST00000453495; = p.Q574Rfs*179 on NM_015005.3) | Frame Shift Del (DEL) | VAF 26/157 reads (17%) | catalogued as rs1431118175; called by mutect2, pindel, varscan2
- CEP170B | c.2656dup p.H886Pfs*47 (on ENST00000453495; = p.H815Pfs*47 on NM_015005.3) | Frame Shift Ins (INS) | VAF 40/175 reads (23%) | catalogued as rs1566868080; called by mutect2, varscan2
- CEP76 | c.295del p.T99Lfs*90 | Frame Shift Del (DEL) | VAF 23/67 reads (34%) | catalogued as rs747064410; called by mutect2, varscan2
- CFAP300 | c.430C>T p.R144* | Nonsense Mutation (SNP) | VAF 40/168 reads (24%) | catalogued as rs762224876; called by muse, mutect2, varscan2
- CFAP46 | c.7214del p.P2405Lfs*5 | Frame Shift Del (DEL) | VAF 30/122 reads (25%) | catalogued as rs1344439240; called by mutect2, varscan2
- CFH | c.140A>G p.Q47R | Missense Mutation (SNP) | VAF 14/200 reads (7%) | SIFT tolerated (0.25); PolyPhen benign (0.197); catalogued as COSV62778708; called by muse, mutect2
- CHD6 | c.3694C>T p.R1232* | Nonsense Mutation (SNP) | VAF 25/101 reads (25%) | catalogued as COSV58556776; called by muse, mutect2, varscan2
- CHRM3 | c.1700del p.K567Rfs*31 | Frame Shift Del (DEL) | VAF 59/206 reads (29%) | catalogued as rs751548647; called by mutect2, varscan2
- CHRNA7 | c.1030C>T p.R344* | Nonsense Mutation (SNP) | VAF 32/226 reads (14%) | catalogued as rs776390894; called by mutect2, varscan2
- CHST6 | c.344G>A p.R115H | Missense Mutation (SNP) | VAF 187/711 reads (26%) | SIFT tolerated (0.1); PolyPhen benign (0.198); catalogued as rs757286105; called by muse, mutect2, varscan2
- CIC | c.4790del p.P1597Hfs*23 | Frame Shift Del (DEL) | VAF 11/29 reads (38%) | catalogued as rs1158987717, COSV50583567; called by mutect2, pindel
- CKAP2 | c.1817del p.K606Rfs*14 (on ENST00000378037 / NM_001098525.2; = p.K605Rfs*14 on NM_018204.5) | Frame Shift Del (DEL) | VAF 26/88 reads (30%) | catalogued as rs752250702; called by mutect2, varscan2
- CKMT1B | c.973C>T p.R325W | Missense Mutation (SNP) | VAF 39/182 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as rs376921959, COSV55851759; called by muse, mutect2, varscan2
- CLINT1 | c.835G>A p.A279T | Missense Mutation (SNP) | VAF 16/512 reads (3%) | SIFT tolerated (0.2); PolyPhen benign (0.035); catalogued as COSV51623673; called by muse, mutect2
- CNN2 | c.185+1G>A p.X62_splice | Splice Site (SNP) | VAF 28/109 reads (26%) | catalogued as rs1302945316; called by muse, mutect2, varscan2
- CNTLN | c.4096A>G p.I1366V | Missense Mutation (SNP) | VAF 30/130 reads (23%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.741); catalogued as rs981918473; called by muse, mutect2, varscan2
- CNTRL | c.5405del p.K1802Sfs*9 | Frame Shift Del (DEL) | VAF 63/278 reads (23%) | catalogued as rs1217756472; called by mutect2, varscan2
- COL4A2 | c.788C>T p.A263V | Missense Mutation (SNP) | VAF 16/240 reads (7%) | SIFT tolerated (0.4); PolyPhen benign (0.005); catalogued as rs1447552664; called by muse, mutect2
- COL4A2 | c.4753C>T p.P1585S | Missense Mutation (SNP) | VAF 98/331 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.463); catalogued as rs1373650840, COSV64631007; called by muse, varscan2
- COLEC12 | c.1740del p.G581Afs*65 | Frame Shift Del (DEL) | VAF 8/37 reads (22%) | catalogued as rs750635929, COSV68369940; called by mutect2, pindel, varscan2
- CPED1 | c.1114A>G p.M372V | Missense Mutation (SNP) | VAF 43/166 reads (26%) | SIFT tolerated (0.6); PolyPhen benign (0.003); catalogued as rs767568660; called by muse, mutect2, varscan2
- CR2 | c.1876G>A p.V626M | Missense Mutation (SNP) | VAF 94/357 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1286870398; called by muse, mutect2, varscan2
- CRACD | c.2219del p.T740Rfs*89 | Frame Shift Del (DEL) | VAF 79/390 reads (20%) | catalogued as COSV99949985; called by mutect2, pindel, varscan2
- CRISP3 | c.799G>T p.A267S (on ENST00000371159 / NM_001368123.1; = p.A249S on NM_006061.4) | Missense Mutation (SNP) | VAF 39/131 reads (30%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.904); catalogued as COSV53821730; called by muse, mutect2, varscan2
- CRLF3 | c.1036_1037del p.L346Afs*9 | Frame Shift Del (DEL) | VAF 50/215 reads (23%) | catalogued as rs912204776; called by pindel, varscan2
- CSNK1A1L | c.690dup p.Q231Tfs*4 | Frame Shift Ins (INS) | VAF 58/315 reads (18%) | catalogued as rs369743261; called by mutect2, varscan2
- CYP7A1 | c.784T>C p.F262L | Missense Mutation (SNP) | VAF 99/406 reads (24%) | SIFT tolerated (0.78); PolyPhen benign (0.001); catalogued as rs1227195073; called by muse, mutect2, varscan2
- DAAM2 | c.3092G>A p.R1031H (on ENST00000274867 / NM_001201427.2; = p.R1030H on NM_015345.3) | Missense Mutation (SNP) | VAF 31/96 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs754072898, COSV99224226; called by muse, mutect2, varscan2
- DAB1 | c.885del p.T296Lfs*70 (on ENST00000371231; = p.T263Lfs*70 on NM_021080.5 and 5 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 10/94 reads (11%) | catalogued as COSV104428367; called by mutect2, pindel
- DACT1 | c.2093G>A p.R698H | Missense Mutation (SNP) | VAF 86/248 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.911); catalogued as rs1369994515, COSV60021323; called by muse, mutect2
- DCAF1 | c.2491C>T p.R831* | Nonsense Mutation (SNP) | VAF 68/210 reads (32%) | catalogued as COSV100244179; called by muse, mutect2, varscan2
- DCST1 | c.1094G>A p.R365H | Missense Mutation (SNP) | VAF 51/151 reads (34%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as rs570204076; called by muse, mutect2, varscan2
- DDHD1 | c.1171C>T p.R391* (on ENST00000323669; = p.R588* on NM_030637.3) | Nonsense Mutation (SNP) | VAF 29/117 reads (25%) | catalogued as rs1394288187, COSV100079262; called by muse, mutect2, varscan2
- DDR2 | c.511G>A p.D171N | Missense Mutation (SNP) | VAF 107/435 reads (25%) | SIFT tolerated (0.1); PolyPhen benign (0.301); catalogued as rs778072557, COSV63370699, COSV63375038; called by muse, mutect2, varscan2
- DDX42 | c.1268C>T p.S423F | Missense Mutation (SNP) | VAF 58/259 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100834910; called by muse, mutect2, varscan2
- DDX46 | c.447+1G>A p.X149_splice | Splice Site (SNP) | VAF 38/136 reads (28%) | catalogued as rs184976178, COSV100844912; called by muse, mutect2, varscan2
- DENND1C | c.491del p.P164Lfs*29 | Frame Shift Del (DEL) | VAF 10/38 reads (26%) | catalogued as rs553532837; called by mutect2, varscan2
- DHX8 | c.1051C>T p.R351W | Missense Mutation (SNP) | VAF 81/328 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.023); catalogued as rs777020341, COSV52255555; called by muse, mutect2, varscan2
- DICER1 | c.5115A>T p.E1705D | Missense Mutation (SNP) | VAF 22/326 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV58622804; called by muse, mutect2
- DIP2A | c.4633C>T p.R1545W | Missense Mutation (SNP) | VAF 40/173 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs753240266; called by muse, mutect2, varscan2
- DLG5 | c.5090G>A p.R1697H | Missense Mutation (SNP) | VAF 57/180 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as rs142696061; called by muse, mutect2, varscan2
- DLL3 | c.1775del p.F592Sfs*26 | Frame Shift Del (DEL) | VAF 91/342 reads (27%) | catalogued as COSV52694505; called by mutect2, pindel, varscan2
- DMC1 | c.667G>A p.D223N | Missense Mutation (SNP) | VAF 86/366 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs748020628, COSV53259905; called by muse, mutect2, varscan2
- DNAH1 | c.5479C>T p.R1827C | Missense Mutation (SNP) | VAF 29/129 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.019); catalogued as rs765753155, COSV70226796; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DNAH3 | c.7462G>A p.V2488M | Missense Mutation (SNP) | VAF 46/141 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs778402685; called by muse, mutect2, varscan2
- DPP10 | c.1730C>T p.T577I | Missense Mutation (SNP) | VAF 34/112 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.395); catalogued as COSV100059362, COSV59684777; called by muse, mutect2
- DRD5 | c.1145C>T p.T382M | Missense Mutation (SNP) | VAF 49/190 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.732); catalogued as rs775864675, COSV58576954; called by muse, mutect2, varscan2
- DST | c.15221C>A p.S5074Y (on ENST00000361203 / NM_001374722.1; = p.S2662Y on NM_015548.5) | Missense Mutation (SNP) | VAF 58/228 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.284); catalogued as COSV55036618; called by muse, varscan2
- DUS4L-BCAP29 | c.1060del p.W354Gfs*2 | Frame Shift Del (DEL) | VAF 26/100 reads (26%) | catalogued as rs746928635; called by mutect2, pindel, varscan2
- DUSP8 | c.983del p.P328Rfs*25 | Frame Shift Del (DEL) | VAF 28/102 reads (27%) | catalogued as COSV100524497, COSV100524514; called by mutect2, pindel, varscan2
- ECE1 | c.1369G>A p.A457T | Missense Mutation (SNP) | VAF 134/556 reads (24%) | SIFT tolerated (0.18); PolyPhen benign (0.005); catalogued as rs1023309311, COSV51660550, COSV51662305; called by muse, mutect2, varscan2
- EDRF1 | c.2635del p.S879Afs*46 (on ENST00000356792 / NM_001202438.2; = p.S845Afs*46 on NM_015608.2) | Frame Shift Del (DEL) | VAF 86/382 reads (23%) | catalogued as rs1388716596, COSV100523284; called by mutect2, varscan2
- EFCAB5 | c.2529del p.F843Lfs*13 | Frame Shift Del (DEL) | VAF 24/220 reads (11%) | catalogued as rs1236463784; called by mutect2, pindel
- EFNB3 | c.532C>T p.R178* | Nonsense Mutation (SNP) | VAF 14/58 reads (24%) | catalogued as rs764233884, COSV56833619; called by muse, mutect2, varscan2
- EGFLAM | c.2515C>T p.Q839* (on ENST00000354891 / NM_001205301.2; = p.Q831* on NM_152403.4) | Nonsense Mutation (SNP) | VAF 48/234 reads (21%) | catalogued as COSV59298861; called by muse, varscan2
- ELL3 | c.421C>T p.Q141* | Nonsense Mutation (SNP) | VAF 110/446 reads (25%) | catalogued as COSV55858037; called by muse, mutect2, varscan2
- ELMO3 | c.1248dup p.G417Rfs*50 (on ENST00000652269; = p.G364Rfs*50 on NM_024712.5) | Frame Shift Ins (INS) | VAF 54/206 reads (26%) | catalogued as rs781430251; called by pindel, varscan2
- ELOA | c.1394del p.N465Mfs*19 | Frame Shift Del (DEL) | VAF 52/230 reads (23%) | catalogued as rs766700925; called by mutect2, varscan2
- EMILIN2 | c.508del p.V170* | Frame Shift Del (DEL) | VAF 18/76 reads (24%) | catalogued as rs1281163907; called by mutect2, pindel
- ENPP7 | c.464C>T p.T155M | Missense Mutation (SNP) | VAF 41/159 reads (26%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.463); catalogued as rs376880357; called by muse, mutect2, varscan2
- ENTHD1 | c.449G>A p.R150H | Missense Mutation (SNP) | VAF 31/141 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs762245558, COSV100288271; called by muse, mutect2, varscan2
- EPDR1 | c.182G>A p.R61H | Missense Mutation (SNP) | VAF 28/139 reads (20%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as COSV99554159; called by muse, mutect2, varscan2
- ERBIN | c.839C>T p.T280M | Missense Mutation (SNP) | VAF 42/175 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.572); catalogued as rs776446365, COSV52319531; called by muse, mutect2, varscan2
- ERI2 | c.8C>T p.T3I | Missense Mutation (SNP) | VAF 49/208 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.881); catalogued as rs770311024; called by muse, mutect2, varscan2
- ERICH2 | c.261del p.K87Nfs*5 | Frame Shift Del (DEL) | VAF 21/72 reads (29%) | catalogued as rs765922748; called by mutect2, pindel, varscan2
- ESPNL | c.2360C>T p.P787L | Missense Mutation (SNP) | VAF 36/130 reads (28%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs1170410356; called by muse, mutect2, varscan2
- ETFDH | c.1198A>G p.T400A | Missense Mutation (SNP) | VAF 17/291 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.031); catalogued as rs1400350320; called by muse, mutect2
- ETV3 | c.665A>G p.H222R | Missense Mutation (SNP) | VAF 54/146 reads (37%) | SIFT tolerated (0.21); PolyPhen benign (0.001); catalogued as rs1454367145; called by muse, mutect2, varscan2
- EVPL | c.4706C>T p.T1569M | Missense Mutation (SNP) | VAF 35/146 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.045); catalogued as rs750250014, COSV100044139; called by muse, mutect2, varscan2
- FAHD2A | c.842del p.P281Qfs*26 | Frame Shift Del (DEL) | VAF 58/209 reads (28%) | catalogued as rs766589051; called by mutect2, pindel, varscan2
- FAM166C | c.20G>A p.G7D | Missense Mutation (SNP) | VAF 73/253 reads (29%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs902387068; called by muse, mutect2, varscan2
- FAM171A1 | c.2572G>A p.E858K | Missense Mutation (SNP) | VAF 54/237 reads (23%) | SIFT tolerated (0.16); PolyPhen benign (0.039); catalogued as rs769373116, COSV100968289, COSV65315866; called by muse, mutect2, varscan2
- FAR2 | c.1208C>T p.T403M | Missense Mutation (SNP) | VAF 36/164 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.953); catalogued as rs184375580; called by muse, mutect2, varscan2
- FARP2 | c.2066G>A p.R689H | Missense Mutation (SNP) | VAF 85/372 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.636); catalogued as rs374552131, COSV50870438; called by muse, mutect2, varscan2
- FASTKD5 | c.767G>A p.R256H | Missense Mutation (SNP) | VAF 48/168 reads (29%) | SIFT tolerated (0.14); PolyPhen benign (0.005); catalogued as rs774251244, COSV53910223; called by muse, mutect2, varscan2
- FAT1 | c.11029G>A p.D3677N | Missense Mutation (SNP) | VAF 119/373 reads (32%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.544); catalogued as rs754963553; called by muse, varscan2
- FAT1 | c.10934T>A p.I3645N | Missense Mutation (SNP) | VAF 88/282 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.398); catalogued as COSV71676225; called by muse, varscan2
- FAT3 | c.10903G>A p.V3635M | Missense Mutation (SNP) | VAF 80/283 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs1271937934; called by muse, mutect2, varscan2
- FBN1 | c.7840G>A p.A2614T | Missense Mutation (SNP) | VAF 131/476 reads (28%) | SIFT tolerated (0.09); PolyPhen benign (0.334); catalogued as rs1280320763; called by muse, mutect2, varscan2
- FBRSL1 | c.814G>A p.A272T | Missense Mutation (SNP) | VAF 29/121 reads (24%) | SIFT tolerated (0.12); PolyPhen benign (0.009); catalogued as rs1041928176, COSV55509635; called by muse, mutect2, varscan2
- FBXO7 | c.1442G>A p.R481H | Missense Mutation (SNP) | VAF 23/230 reads (10%) | SIFT tolerated (0.32); PolyPhen benign (0.039); catalogued as rs766854590, COSV99832655; called by muse, mutect2
- FCHO1 | c.2405G>A p.R802H | Missense Mutation (SNP) | VAF 97/340 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.005); catalogued as rs771940414, COSV53181477; called by muse, mutect2, varscan2
- FEZF1 | c.1337C>T p.P446L | Missense Mutation (SNP) | VAF 68/278 reads (24%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0); catalogued as rs758243120; called by muse, mutect2, varscan2
- FIZ1 | c.230G>A p.R77Q | Missense Mutation (SNP) | VAF 73/238 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.933); catalogued as COSV55607845; called by muse, mutect2, varscan2
- FKBP15 | c.1994del p.K665Rfs*9 | Frame Shift Del (DEL) | VAF 40/168 reads (24%) | catalogued as rs774060142; called by mutect2, varscan2
- FKBP5 | c.1369G>A p.V457I | Missense Mutation (SNP) | VAF 44/136 reads (32%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.015); catalogued as rs767540520, COSV61879587; called by muse, mutect2, varscan2
- FMO3 | c.712C>T p.R238* | Nonsense Mutation (SNP) | VAF 66/230 reads (29%) | catalogued as rs893223321, COSV100882422; called by muse, mutect2, varscan2
- FOXK1 | c.917C>T p.P306L | Missense Mutation (SNP) | VAF 33/104 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV61064746; called by muse, mutect2, varscan2
- FPGT-TNNI3K | c.808C>T p.H270Y | Missense Mutation (SNP) | VAF 43/196 reads (22%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.543); catalogued as rs777094504; called by muse, mutect2, varscan2
- FREM2 | c.4477T>C p.Y1493H | Missense Mutation (SNP) | VAF 79/318 reads (25%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.605); catalogued as COSV99751885; called by muse, mutect2, varscan2
- FSCN3 | c.385G>A p.V129I | Missense Mutation (SNP) | VAF 69/237 reads (29%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.543); catalogued as rs758448650, COSV50001654; called by muse, mutect2, varscan2
- FST | c.431C>T p.A144V | Missense Mutation (SNP) | VAF 81/331 reads (24%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.953); catalogued as rs762675925; called by muse, mutect2, varscan2
- GALNT17 | c.1141C>T p.R381W | Missense Mutation (SNP) | VAF 53/178 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs758121306, COSV100353306, COSV61160204; called by muse, mutect2, varscan2
- GAS6 | c.449del p.G150Afs*49 | Frame Shift Del (DEL) | VAF 37/160 reads (23%) | catalogued as rs773341392; called by mutect2, pindel, varscan2
- GATAD2A | c.1805C>T p.A602V | Missense Mutation (SNP) | VAF 47/229 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.114); catalogued as rs751719552; called by muse, mutect2, varscan2
- GBGT1 | c.949G>A p.E317K | Missense Mutation (SNP) | VAF 31/111 reads (28%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as rs151100399; called by muse, mutect2, varscan2
- GBP4 | c.157G>A p.V53M | Missense Mutation (SNP) | VAF 28/157 reads (18%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.984); catalogued as rs200823724, COSV100864336; called by muse, mutect2, varscan2
- GCDH | c.745A>G p.R249G | Missense Mutation (SNP) | VAF 95/412 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.025); catalogued as rs750692764; called by muse, mutect2, varscan2
- GCM1 | c.377G>A p.R126Q | Missense Mutation (SNP) | VAF 63/277 reads (23%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); catalogued as rs375109372; called by muse, mutect2, varscan2
- GDF11 | c.136del p.E46Sfs*31 | Frame Shift Del (DEL) | VAF 7/27 reads (26%) | catalogued as rs1412840296; called by mutect2, pindel, varscan2
- GJA9 | c.1522C>T p.R508W | Missense Mutation (SNP) | VAF 32/117 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs866850832; called by muse, mutect2, varscan2
- GJB6 | c.404C>T p.T135M | Missense Mutation (SNP) | VAF 100/379 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs1566538446, CM078517, COSV53832867; called by muse, mutect2, varscan2
- GLI2 | c.3028C>T p.R1010W (on ENST00000361492 / NM_001374353.1; = p.R1027W on NM_005270.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 80/242 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs1404870952, COSV100083087; called by muse, mutect2, varscan2
- GMIP | c.1733G>A p.R578H | Missense Mutation (SNP) | VAF 24/113 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs868056029, COSV52558105; called by muse, mutect2, varscan2
- GNAI1 | c.1037del p.N346Ifs*3 | Frame Shift Del (DEL) | VAF 17/65 reads (26%) | catalogued as COSV100650464; called by mutect2, pindel
- GPR135 | c.1198C>T p.R400C | Missense Mutation (SNP) | VAF 51/236 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV67749879; called by muse, mutect2, varscan2
- GPR52 | c.912G>A p.W304* | Nonsense Mutation (SNP) | VAF 9/133 reads (7%) | catalogued as COSV99275722; called by muse, mutect2
- GSE1 | c.366del p.V123Wfs*2 | Frame Shift Del (DEL) | VAF 22/74 reads (30%) | catalogued as rs754199513; called by mutect2, varscan2
- GSS | c.394C>T p.R132C | Missense Mutation (SNP) | VAF 105/412 reads (25%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as rs202195412, COSV53813430; called by muse, mutect2, varscan2
- H1-2 | c.514A>G p.K172E | Missense Mutation (SNP) | VAF 80/352 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.985); catalogued as rs1213947732; called by muse, mutect2, varscan2
- HCFC1R1 | c.249del p.M84* | Frame Shift Del (DEL) | VAF 12/47 reads (26%) | catalogued as rs746547303; called by mutect2, pindel, varscan2
- HDGF | c.149del p.F50Sfs*105 | Frame Shift Del (DEL) | VAF 81/154 reads (53%) | catalogued as COSV100625709; called by mutect2, varscan2
- HDGFL2 | c.1151G>A p.R384Q | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.712); catalogued as rs190117333; called by muse, varscan2
- HDLBP | c.3289-3del | Splice Region (DEL) | VAF 24/87 reads (28%) | catalogued as rs778255938; called by mutect2, pindel, varscan2
- HERC2 | c.9859G>A p.G3287S | Missense Mutation (SNP) | VAF 41/215 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV55309025; called by muse, mutect2, varscan2
- HIPK4 | c.756C>A p.N252K | Missense Mutation (SNP) | VAF 52/183 reads (28%) | SIFT tolerated (0.23); PolyPhen benign (0.014); catalogued as rs199630536; called by muse, mutect2, varscan2
- HIVEP3 | c.776A>G p.Y259C | Missense Mutation (SNP) | VAF 28/134 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.848); catalogued as COSV56018047; called by muse, mutect2, varscan2
- HK2 | c.736G>A p.D246N | Missense Mutation (SNP) | VAF 63/228 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.6); catalogued as rs774427032, COSV51874265; called by muse, mutect2, varscan2
- HPCAL4 | c.280C>T p.R94C | Missense Mutation (SNP) | VAF 48/414 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1557753600; called by muse, mutect2, varscan2
- HRNR | c.2383G>A p.G795R | Missense Mutation (SNP) | VAF 83/318 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.014); catalogued as rs1208286406, COSV64254370; called by muse, mutect2, varscan2
- HS3ST6 | c.613C>T p.R205C | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.806); catalogued as rs201954014, COSV99562930; called by muse, mutect2, varscan2
- HSP90B1 | c.1403C>T p.T468M | Missense Mutation (SNP) | VAF 41/168 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.868); catalogued as rs772910819; called by muse, mutect2, varscan2
- IGFBP4 | c.123del p.V42Wfs*52 | Frame Shift Del (DEL) | VAF 46/185 reads (25%) | catalogued as rs778799414; called by mutect2, pindel, varscan2
- IGSF22 | c.946C>T p.R316W | Missense Mutation (SNP) | VAF 39/143 reads (27%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.877); catalogued as rs369682932; called by muse, mutect2, varscan2
- IGSF9 | c.2284C>T p.R762W (on ENST00000368094 / NM_001135050.2; = p.R746W on NM_020789.4) | Missense Mutation (SNP) | VAF 50/137 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.53); catalogued as rs375167066; called by muse, mutect2, varscan2
- IL11 | c.540del p.L181Cfs*3 | Frame Shift Del (DEL) | VAF 89/309 reads (29%) | catalogued as COSV99214838; called by mutect2, pindel, varscan2
- IL17RC | c.391G>A p.V131M (on ENST00000295981 / NM_153461.4; = p.V60M on NM_032732.6 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 64/337 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs201975186; called by muse, mutect2, varscan2
- IL2RG | c.1082del p.P361Hfs*5 | Frame Shift Del (DEL) | VAF 6/10 reads (60%) | catalogued as rs745545309; called by mutect2, varscan2
- INPPL1 | c.3466del p.R1156Gfs*46 | Frame Shift Del (DEL) | VAF 33/128 reads (26%) | catalogued as rs760925109; called by mutect2, pindel, varscan2
- INTS11 | c.554G>A p.R185Q | Missense Mutation (SNP) | VAF 85/369 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.629); catalogued as rs760073251, COSV60088144; called by muse, mutect2, varscan2
- ITGB3 | c.869G>T p.G290V | Missense Mutation (SNP) | VAF 66/219 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs781625616; called by muse, mutect2, varscan2
- JAK1 | c.1289del p.P430Rfs*2 | Frame Shift Del (DEL) | VAF 31/102 reads (30%) | catalogued as rs755650243; called by mutect2, pindel, varscan2
- JAK1 | c.520C>T p.R174* | Nonsense Mutation (SNP) | VAF 42/168 reads (25%) | catalogued as COSV61087251; called by muse, mutect2, varscan2
- JPH3 | c.1060del p.L354Cfs*117 | Frame Shift Del (DEL) | VAF 88/369 reads (24%) | catalogued as COSV52470301; called by mutect2, pindel, varscan2
- JUN | c.283A>G p.T95A | Missense Mutation (SNP) | VAF 9/143 reads (6%) | SIFT tolerated (0.46); PolyPhen benign (0.022); catalogued as COSV64664826; called by muse, mutect2
- KANK4 | c.334C>T p.L112F | Missense Mutation (SNP) | VAF 38/171 reads (22%) | SIFT tolerated (0.71); PolyPhen possibly damaging (0.459); catalogued as COSV62988982; called by muse, mutect2, varscan2
- KCNA10 | c.992C>T p.A331V | Missense Mutation (SNP) | VAF 85/298 reads (29%) | SIFT tolerated (0.05); PolyPhen benign (0.081); catalogued as COSV63904518; called by muse, mutect2, varscan2
- KCND2 | c.419G>A p.R140H | Missense Mutation (SNP) | VAF 56/207 reads (27%) | SIFT tolerated (0.09); PolyPhen benign (0.048); catalogued as rs756823168, COSV58586030; called by muse, mutect2, varscan2
- KCND3 | c.772G>A p.V258I | Missense Mutation (SNP) | VAF 77/269 reads (29%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.459); catalogued as COSV56188258; called by muse, mutect2, varscan2
- KCNG1 | c.1028G>A p.R343H | Missense Mutation (SNP) | VAF 14/178 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1473799992; called by muse, mutect2
- KCNH2 | c.2201G>A p.R734H | Missense Mutation (SNP) | VAF 59/238 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV51139400; called by muse, mutect2, varscan2
- KCNN1 | c.1582C>T p.R528W | Missense Mutation (SNP) | VAF 15/74 reads (20%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0); catalogued as rs1012293888; called by muse, mutect2, varscan2
- KCTD21 | c.638C>T p.A213V | Missense Mutation (SNP) | VAF 76/331 reads (23%) | SIFT tolerated (0.23); PolyPhen benign (0.034); catalogued as rs780030980; called by muse, mutect2, varscan2
- KCTD8 | c.845G>A p.R282H | Missense Mutation (SNP) | VAF 33/137 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.925); catalogued as COSV100759493, COSV63591325; called by muse, mutect2, varscan2
- KIAA0232 | c.2162G>A p.R721H | Missense Mutation (SNP) | VAF 34/128 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1264348101; called by muse, mutect2, varscan2
- KIF19 | c.2362C>T p.R788W | Missense Mutation (SNP) | VAF 43/169 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as rs368454219; called by muse, mutect2, varscan2
- KIF26A | c.4882G>A p.G1628S | Missense Mutation (SNP) | VAF 23/104 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1271236636; called by muse, mutect2, varscan2
- KLF5 | c.905del p.P302Rfs*21 | Frame Shift Del (DEL) | VAF 70/238 reads (29%) | catalogued as COSV66614378, COSV66615313; called by mutect2, pindel, varscan2
- KLHDC8B | c.48del p.M17Cfs*59 | Frame Shift Del (DEL) | VAF 40/148 reads (27%) | catalogued as rs756907493; called by mutect2, pindel
- KLHL26 | c.1129G>A p.E377K | Missense Mutation (SNP) | VAF 40/149 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.024); catalogued as COSV56316834; called by muse, mutect2, varscan2
- KLHL29 | c.1084G>A p.V362M | Missense Mutation (SNP) | VAF 72/278 reads (26%) | SIFT tolerated (0.25); PolyPhen benign (0.003); catalogued as rs368416333; called by muse, mutect2
- KLHL29 | c.1996G>A p.V666I | Missense Mutation (SNP) | VAF 55/219 reads (25%) | SIFT tolerated (0.19); PolyPhen benign (0.28); catalogued as COSV56022123; called by muse, mutect2, varscan2
- KLHL9 | c.81dup p.T28Yfs*14 | Frame Shift Ins (INS) | VAF 35/103 reads (34%) | catalogued as rs755553508; called by mutect2, pindel, varscan2
- KMT2B | c.5636del p.G1879Vfs*16 | Frame Shift Del (DEL) | VAF 44/181 reads (24%) | catalogued as COSV55868319; called by mutect2, varscan2
- KMT5C | c.800G>A p.R267Q | Missense Mutation (SNP) | VAF 70/262 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.285); catalogued as rs1483159807; called by muse, mutect2, varscan2
- KNTC1 | c.1709G>A p.R570Q | Missense Mutation (SNP) | VAF 58/242 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs781762358, COSV100338267; called by muse, mutect2, varscan2
- KRIT1 | c.1354C>T p.R452C | Missense Mutation (SNP) | VAF 52/276 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as rs1480771068, COSV60670506; called by muse, mutect2, varscan2
- KRTAP10-8 | c.767G>A p.R256H | Missense Mutation (SNP) | VAF 46/164 reads (28%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as rs753364581; called by muse, mutect2
- L34079.1 | c.146C>T p.A49V | Missense Mutation (SNP) | VAF 139/436 reads (32%) | SIFT deleterious (0.05); PolyPhen benign (0.03); catalogued as rs1392318784, COSV60670890; called by muse, mutect2, varscan2
- L3MBTL1 | c.652C>T p.R218W (on ENST00000418998 / NM_001377303.1; = p.R128W on NM_015478.7) | Missense Mutation (SNP) | VAF 42/184 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs774524586, COSV64231875; called by muse, mutect2, varscan2
- LARP7 | c.173G>A p.R58Q | Missense Mutation (SNP) | VAF 49/187 reads (26%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.971); catalogued as rs750414935; called by muse, mutect2, varscan2
- LCE1B | c.92del p.P31Qfs*47 | Frame Shift Del (DEL) | VAF 86/345 reads (25%) | catalogued as COSV63980354; called by mutect2, pindel, varscan2
- LIG3 | c.395del p.G132Vfs*3 | Frame Shift Del (DEL) | VAF 65/287 reads (23%) | catalogued as COSV52005906; called by mutect2, pindel, varscan2
- LILRB1 | c.587_589del p.G196del (on ENST00000427581; = p.G160del on NM_006669.6) | In Frame Del (DEL) | VAF 55/421 reads (13%) | catalogued as rs1298312608; called by mutect2, pindel, varscan2
- LMCD1 | c.838G>A p.E280K | Missense Mutation (SNP) | VAF 94/308 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.889); catalogued as rs768952160; called by muse, mutect2, varscan2
- LMO2 | c.283G>A p.A95T (on ENST00000395833 / NM_001142315.2; = p.A164T on NM_005574.4) | Missense Mutation (SNP) | VAF 65/217 reads (30%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.996); catalogued as rs1194594724; called by muse, mutect2, varscan2
- LONP1 | c.1574dup p.G526Wfs*4 | Frame Shift Ins (INS) | VAF 18/53 reads (34%) | catalogued as rs888845599; called by mutect2, pindel, varscan2
- LOXHD1 | c.5869G>A p.D1957N (on ENST00000642948; = p.D1895N on NM_144612.7) | Missense Mutation (SNP) | VAF 33/123 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1463723392; called by muse, mutect2, varscan2
- LOXL3 | c.1213C>T p.R405W | Missense Mutation (SNP) | VAF 26/76 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs995890167, COSV51214214; called by muse, mutect2, varscan2
- LRP1 | c.10234G>A p.V3412I | Missense Mutation (SNP) | VAF 31/151 reads (21%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.989); catalogued as rs150254492; called by muse, mutect2, varscan2
- LRP10 | c.95del p.P32Qfs*5 | Frame Shift Del (DEL) | VAF 21/82 reads (26%) | catalogued as COSV62078437; called by mutect2, pindel, varscan2
- LRRC43 | c.1680del p.I561Sfs*10 | Frame Shift Del (DEL) | VAF 64/257 reads (25%) | catalogued as rs748039371; called by mutect2, pindel, varscan2
- LRRC8A | c.1585G>A p.A529T | Missense Mutation (SNP) | VAF 48/170 reads (28%) | SIFT tolerated (0.82); PolyPhen benign (0.146); catalogued as rs377359713; called by muse, mutect2, varscan2
- LYN | c.1486G>A p.V496I | Missense Mutation (SNP) | VAF 53/270 reads (20%) | SIFT tolerated (0.13); PolyPhen benign (0.11); catalogued as rs527508795, COSV72923437; called by muse, mutect2, varscan2
- LYRM1 | c.67T>C p.W23R | Missense Mutation (SNP) | VAF 38/172 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54643620; called by muse, mutect2, varscan2
- MAFG | c.421G>A p.V141I | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT tolerated, low confidence (0.96); PolyPhen benign (0); catalogued as rs774502626; called by muse, mutect2, varscan2
- MAGEC1 | c.2473C>G p.L825V | Missense Mutation (SNP) | VAF 15/123 reads (12%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.134); catalogued as COSV99596765; called by muse, mutect2, varscan2
- MALRD1 | c.4590G>A p.W1530* | Nonsense Mutation (SNP) | VAF 18/254 reads (7%) | catalogued as rs867176306; called by muse, mutect2
- MAP1A | c.6193del p.R2065Vfs*5 | Frame Shift Del (DEL) | VAF 26/103 reads (25%) | catalogued as COSV55811343; called by mutect2, pindel, varscan2
- MAP2K7 | c.875del p.P292Qfs*119 | Frame Shift Del (DEL) | VAF 51/171 reads (30%) | catalogued as COSV67608111; called by mutect2, pindel, varscan2
- MAP3K19 | c.2971dup p.M991Nfs*4 | Frame Shift Ins (INS) | VAF 30/127 reads (24%) | catalogued as rs1047513406; called by mutect2, pindel, varscan2
- MAPK15 | c.1355C>T p.A452V | Missense Mutation (SNP) | VAF 38/162 reads (23%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as rs1554619968; called by muse, mutect2, varscan2
- MARCKS | c.980del p.P327Qfs*42 | Frame Shift Del (DEL) | VAF 30/122 reads (25%) | catalogued as rs770972906; called by mutect2, pindel, varscan2
- MAST2 | c.3400C>T p.H1134Y | Missense Mutation (SNP) | VAF 67/229 reads (29%) | SIFT tolerated, low confidence (0.05); PolyPhen possibly damaging (0.707); catalogued as COSV63621474; called by muse, mutect2, varscan2
- MCM5 | c.1621G>A p.V541M | Missense Mutation (SNP) | VAF 36/149 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.027); catalogued as rs138322887; called by muse, mutect2, varscan2
- MDN1 | c.2905C>T p.R969W | Missense Mutation (SNP) | VAF 53/221 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs759265310, COSV65518089; called by muse, mutect2, varscan2
- MDN1 | c.737G>A p.R246H | Missense Mutation (SNP) | VAF 42/158 reads (27%) | SIFT tolerated (0.73); PolyPhen benign (0.003); catalogued as rs375183845; called by muse, mutect2, varscan2
- MED23 | c.1222-2A>G p.X408_splice | Splice Site (SNP) | VAF 59/255 reads (23%) | catalogued as COSV100645013, COSV63433304; called by muse, mutect2, varscan2
- METTL3 | c.397C>T p.R133* | Nonsense Mutation (SNP) | VAF 33/143 reads (23%) | catalogued as rs1230279458, COSV52969151; called by muse, mutect2, varscan2
- MEX3A | c.700G>A p.V234M | Missense Mutation (SNP) | VAF 50/183 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV68479372; called by muse, mutect2, varscan2
- MICU1 | c.849dup p.G284Wfs*3 (on ENST00000361114 / NM_001195518.2; = p.G290Wfs*3 on NM_006077.3 and 1 other RefSeq transcript) | Frame Shift Ins (INS) | VAF 58/254 reads (23%) | catalogued as rs767345966; called by mutect2, pindel, varscan2
- MICU2 | c.188G>A p.G63D | Missense Mutation (SNP) | VAF 15/218 reads (7%) | SIFT tolerated (0.3); PolyPhen benign (0.003); catalogued as rs912443181; called by muse, mutect2
- MINAR1 | c.2097A>T p.L699F | Missense Mutation (SNP) | VAF 49/185 reads (26%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.942); catalogued as COSV59581461; called by muse, mutect2, varscan2
- MLC1 | c.135del p.C46Afs*12 | Frame Shift Del (DEL) | VAF 123/431 reads (29%) | catalogued as CD151534; called by mutect2, varscan2
- MLLT3 | c.446G>A p.S149N | Missense Mutation (SNP) | VAF 114/418 reads (27%) | SIFT tolerated (0.39); PolyPhen benign (0.007); catalogued as COSV63497807; called by muse, varscan2
- MMP20 | c.1404G>T p.K468N | Missense Mutation (SNP) | VAF 66/324 reads (20%) | SIFT tolerated (0.13); PolyPhen benign (0.261); catalogued as COSV99497900; called by muse, mutect2, varscan2
- MRI1 | c.988del p.H330Tfs*24 (on ENST00000040663 / NM_001031727.4; = p.H283Tfs*24 on NM_032285.4 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 38/118 reads (32%) | catalogued as rs751646149; called by mutect2, varscan2
- MROH5 | c.3452C>T p.A1151V | Missense Mutation (SNP) | VAF 32/150 reads (21%) | SIFT tolerated (0.21); PolyPhen benign (0.026); catalogued as rs978264632; called by muse, mutect2, varscan2
- MROH5 | c.2263C>T p.Q755* | Nonsense Mutation (SNP) | VAF 19/66 reads (29%) | catalogued as rs1316582671; called by muse, mutect2, varscan2
- MRPL11 | c.446G>A p.R149H | Missense Mutation (SNP) | VAF 25/108 reads (23%) | SIFT tolerated (0.22); PolyPhen benign (0.136); catalogued as rs764880801; called by muse, mutect2, varscan2
- MSI1 | c.77del p.G26Dfs*21 | Frame Shift Del (DEL) | VAF 38/144 reads (26%) | catalogued as rs1490523146; called by mutect2, pindel, varscan2
- MST1 | c.547T>C p.C183R | Missense Mutation (SNP) | VAF 22/414 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99610589; called by muse, mutect2
- MTSS2 | c.202C>T p.R68* | Nonsense Mutation (SNP) | VAF 39/141 reads (28%) | catalogued as rs1191503890; called by muse, mutect2, varscan2
- MUC16 | c.41718T>C p.G13906= | Splice Region (SNP) | VAF 22/106 reads (21%) | catalogued as rs796540521; called by muse, mutect2, varscan2
- MUC16 | c.8807del p.N2936Tfs*6 | Frame Shift Del (DEL) | VAF 56/258 reads (22%) | catalogued as COSV101198428, COSV104431809; called by mutect2, pindel, varscan2
- MUC5B | c.3539G>A p.R1180Q | Missense Mutation (SNP) | VAF 11/48 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.328); catalogued as rs375714233; called by muse, mutect2
- MUC5B | c.4517G>A p.R1506Q | Missense Mutation (SNP) | VAF 42/143 reads (29%) | SIFT tolerated (0.2); PolyPhen benign (0.02); catalogued as rs368365490; called by muse, mutect2, varscan2
- MXRA5 | c.6094G>A p.G2032R | Missense Mutation (SNP) | VAF 38/106 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1363623006; called by muse, mutect2, varscan2
- MYCBPAP | c.473C>T p.A158V | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.275); catalogued as rs752306194; called by muse, mutect2, varscan2
- MYH3 | c.5732C>T p.A1911V | Missense Mutation (SNP) | VAF 98/357 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.954); catalogued as rs1439372634; called by muse, mutect2, varscan2
- MYH6 | c.68G>A p.R23H | Missense Mutation (SNP) | VAF 130/463 reads (28%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.77); catalogued as rs771786844; ClinVar: uncertain significance; called by muse, varscan2
- MYLK | c.3526G>A p.A1176T | Missense Mutation (SNP) | VAF 124/408 reads (30%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.914); catalogued as rs758839208; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MYO15A | c.7534G>A p.V2512M | Missense Mutation (SNP) | VAF 54/167 reads (32%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.95); catalogued as rs201619309; called by muse, mutect2, varscan2
- MYO15B | c.5171del p.P1724Rfs*63 | Frame Shift Del (DEL) | VAF 17/65 reads (26%) | catalogued as rs1345750150; called by mutect2, pindel, varscan2
- MYO16 | c.2525del p.F842Sfs*17 | Frame Shift Del (DEL) | VAF 28/94 reads (30%) | catalogued as rs761471964; called by mutect2, varscan2
- NAT14 | c.569dup p.W191Lfs*35 | Frame Shift Ins (INS) | VAF 34/166 reads (20%) | catalogued as rs762319997; called by mutect2, pindel, varscan2
- NCAN | c.3317G>T p.R1106L | Missense Mutation (SNP) | VAF 104/380 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as COSV53051755; called by muse, mutect2, varscan2
- NCBP1 | c.1280G>A p.R427H | Missense Mutation (SNP) | VAF 15/93 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.96); catalogued as rs529407443, COSV64317141; called by muse, mutect2, varscan2
- NDN | c.424C>T p.R142C | Missense Mutation (SNP) | VAF 47/187 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.759); catalogued as COSV100086175, COSV59358609; called by muse, mutect2, varscan2
- NECTIN2 | c.643G>A p.G215R | Missense Mutation (SNP) | VAF 118/455 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs762229036, COSV52977551; called by muse, mutect2, varscan2
- NKPD1 | c.367G>A p.A123T | Missense Mutation (SNP) | VAF 6/61 reads (10%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.027); catalogued as rs973031616; called by muse, mutect2, varscan2
- NKX1-1 | c.505G>A p.D169N | Missense Mutation (SNP) | VAF 39/209 reads (19%) | SIFT deleterious, low confidence (0.04); catalogued as rs1209221245; called by muse, mutect2, varscan2
- NLRP8 | c.533_535del p.F178del | In Frame Del (DEL) | VAF 82/290 reads (28%) | catalogued as rs773103156; called by pindel, varscan2
- NOD2 | c.2473A>G p.N825D | Missense Mutation (SNP) | VAF 12/346 reads (3%) | SIFT deleterious (0); PolyPhen benign (0.416); catalogued as rs1436148419; called by muse, mutect2
- NOS3 | c.613C>T p.Q205* | Nonsense Mutation (SNP) | VAF 45/189 reads (24%) | catalogued as rs1375693812; called by muse, mutect2, varscan2
- NOS3 | c.1319del p.G440Afs*64 | Frame Shift Del (DEL) | VAF 53/202 reads (26%) | catalogued as rs749517498, COSV52496454; called by mutect2, pindel, varscan2
- NOTCH1 | c.4411G>A p.A1471T | Missense Mutation (SNP) | VAF 74/307 reads (24%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.877); catalogued as rs1414066424, COSV53081256; called by muse, mutect2, varscan2
- NPAT | c.4222A>G p.S1408G | Missense Mutation (SNP) | VAF 63/267 reads (24%) | SIFT tolerated (0.29); PolyPhen benign (0.006); catalogued as rs746137328; called by muse, mutect2, varscan2
- NPEPL1 | c.1465C>T p.R489C | Missense Mutation (SNP) | VAF 41/164 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.28); catalogued as rs779600933; called by muse, mutect2, varscan2
- NPFFR1 | c.1132C>T p.P378S | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT tolerated (0.22); PolyPhen benign (0.1); catalogued as rs780383175; called by mutect2, varscan2
- NUP205 | c.4231+8del p.X1411_splice | Splice Site (DEL) | VAF 25/131 reads (19%) | catalogued as rs748861286; called by mutect2, pindel, varscan2
- NUP93 | c.2203A>G p.R735G | Missense Mutation (SNP) | VAF 17/172 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.245); catalogued as rs771748377; called by muse, mutect2
- OBSCN | c.16040G>A p.R5347Q | Missense Mutation (SNP) | VAF 16/47 reads (34%) | SIFT tolerated (0.1); PolyPhen benign (0.139); catalogued as rs758059703, COSV99482528; called by muse, mutect2, varscan2
- OLFML2A | c.151T>C p.C51R | Missense Mutation (SNP) | VAF 22/248 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs931859037; called by muse, mutect2
- OR13J1 | c.548C>T p.A183V | Missense Mutation (SNP) | VAF 68/269 reads (25%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as rs1564059364; called by muse, mutect2, varscan2
- OR14K1 | c.184C>T p.R62* | Nonsense Mutation (SNP) | VAF 55/183 reads (30%) | catalogued as rs550707389; called by muse, mutect2, varscan2
- OR2J2 | c.376G>A p.A126T | Missense Mutation (SNP) | VAF 40/114 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as COSV65847939; called by muse, mutect2, varscan2
- OR3A3 | c.712C>T p.R238C | Missense Mutation (SNP) | VAF 90/423 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.047); catalogued as rs762561652, COSV52168001, COSV52168316; called by muse, mutect2, varscan2
- OR4D2 | c.364C>T p.R122C | Missense Mutation (SNP) | VAF 179/633 reads (28%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.932); catalogued as rs779381707, COSV73459833; called by muse, mutect2, varscan2
- OR4K5 | c.535del p.C179Vfs*20 | Frame Shift Del (DEL) | VAF 69/403 reads (17%) | catalogued as rs1566497842; called by mutect2, varscan2
- OR5B3 | c.476G>T p.G159V | Missense Mutation (SNP) | VAF 26/146 reads (18%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.151); catalogued as rs1253869329, COSV58676477, COSV58678987; called by muse, mutect2, varscan2
- OR8B12 | c.362G>A p.R121H | Missense Mutation (SNP) | VAF 36/142 reads (25%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.902); catalogued as rs369152224, COSV60912115; called by muse, mutect2, varscan2
- OSBPL11 | c.588del p.F196Lfs*11 | Frame Shift Del (DEL) | VAF 52/256 reads (20%) | catalogued as rs1197042783; called by mutect2, pindel, varscan2
- P2RY8 | c.719C>T p.A240V | Missense Mutation (SNP) | VAF 60/202 reads (30%) | SIFT tolerated (0.89); PolyPhen benign (0.023); catalogued as rs751008443, COSV67176987; called by muse, mutect2, varscan2
- PAPPA | c.3127G>T p.G1043* | Nonsense Mutation (SNP) | VAF 30/134 reads (22%) | catalogued as COSV60279080; called by muse, mutect2
- PAX9 | c.370A>G p.S124G | Missense Mutation (SNP) | VAF 155/585 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs768500570; called by muse, mutect2, varscan2
- PCDHA3 | c.596del p.N199Ifs*2 | Frame Shift Del (DEL) | VAF 43/168 reads (26%) | catalogued as rs782411180, COSV65371489; called by mutect2, varscan2
- PCDHA4 | c.1928C>T p.P643L | Missense Mutation (SNP) | VAF 13/413 reads (3%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.024); catalogued as rs17844284, COSV63540047; called by muse, mutect2
- PCDHA9 | c.1612C>T p.R538C | Missense Mutation (SNP) | VAF 274/942 reads (29%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.082); catalogued as rs782219075, COSV65329183; called by muse, mutect2, varscan2
- PCDHGA1 | c.1753G>A p.G585S | Missense Mutation (SNP) | VAF 111/391 reads (28%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.983); catalogued as COSV65295584; called by muse, mutect2, varscan2
- PCED1B | c.835C>T p.P279S | Missense Mutation (SNP) | VAF 33/113 reads (29%) | SIFT tolerated (0.24); PolyPhen benign (0.001); catalogued as rs988913552; called by muse, mutect2, varscan2
- PCSK5 | c.2276G>T p.G759V | Missense Mutation (SNP) | VAF 30/139 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV65086536; called by muse, mutect2, varscan2
- PDE11A | c.434C>T p.A145V | Missense Mutation (SNP) | VAF 49/223 reads (22%) | SIFT tolerated (0.19); PolyPhen benign (0.107); catalogued as rs904847231; called by muse, mutect2, varscan2
- PDE1C | c.137G>T p.R46L | Missense Mutation (SNP) | VAF 34/92 reads (37%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.567); catalogued as rs1212173298, COSV101275383, COSV101275526; called by muse, mutect2, varscan2
- PDHB | c.935-5_935-3del | Splice Region (DEL) | VAF 46/214 reads (21%) | catalogued as rs770061802; called by mutect2, pindel, varscan2
- PDZD8 | c.1570C>T p.R524C | Missense Mutation (SNP) | VAF 52/284 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.763); catalogued as rs376740052; called by muse, mutect2, varscan2
- PELP1 | c.2392del p.L798Cfs*14 | Frame Shift Del (DEL) | VAF 39/129 reads (30%) | catalogued as rs752653446, COSV99342923; called by mutect2, pindel, varscan2
- PGAP4 | c.295del p.R99Gfs*5 | Frame Shift Del (DEL) | VAF 18/81 reads (22%) | catalogued as rs765092936; called by mutect2, varscan2
- PHF2 | c.1475del p.K492Rfs*6 | Frame Shift Del (DEL) | VAF 44/163 reads (27%) | catalogued as rs769717544; called by mutect2, varscan2
- PHF20L1 | c.275_277del p.E92del | In Frame Del (DEL) | VAF 54/166 reads (33%) | catalogued as rs764130703; called by pindel, varscan2
- PHF3 | c.2910dup p.R971Sfs*6 | Frame Shift Ins (INS) | VAF 28/110 reads (25%) | catalogued as rs755026826; called by mutect2, varscan2
- PIN4 | c.419C>T p.P140L (on ENST00000664196; = p.P115L on NM_006223.4) | Missense Mutation (SNP) | VAF 53/138 reads (38%) | SIFT tolerated (0.2); PolyPhen benign (0.311); catalogued as rs1373543056, COSV104374198; called by muse, mutect2, varscan2
- PKN2 | c.1042C>T p.R348W | Missense Mutation (SNP) | VAF 35/127 reads (28%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs770594472, COSV60131780; called by muse, mutect2, varscan2
- PLEC | c.10613C>T p.P3538L (on ENST00000322810 / NM_201380.4; = p.P3428L on NM_000445.5) | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT deleterious (0.05); PolyPhen probably damaging (1); catalogued as COSV59622103; called by muse, mutect2, varscan2
- PLEC | c.9239G>T p.R3080L (on ENST00000322810 / NM_201380.4; = p.R2970L on NM_000445.5) | Missense Mutation (SNP) | VAF 30/581 reads (5%) | SIFT deleterious (0.04); PolyPhen benign (0.082); catalogued as COSV59681013; called by muse, mutect2
- PLEC | c.1952G>A p.R651H (on ENST00000322810 / NM_201380.4; = p.R541H on NM_000445.5) | Missense Mutation (SNP) | VAF 71/279 reads (25%) | SIFT tolerated (0.08); PolyPhen benign (0.011); catalogued as rs781887816, COSV100509586; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PLPPR2 | c.464C>T p.T155M | Missense Mutation (SNP) | VAF 75/245 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV52263113; called by muse, mutect2, varscan2
- PLPPR3 | c.1762C>T p.P588S (on ENST00000520876 / NM_001270366.2; = p.P616S on NM_024888.2) | Missense Mutation (SNP) | VAF 26/138 reads (19%) | SIFT tolerated (0.14); PolyPhen benign (0.177); catalogued as COSV100608939; called by muse, mutect2, varscan2
- PMEL | c.1412T>C p.V471A | Missense Mutation (SNP) | VAF 20/115 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs752922513; called by muse, mutect2, varscan2
- PNCK | c.633del p.F212Sfs*14 (on ENST00000340888 / NM_001366975.1; = p.F295Sfs*14 on NM_001039582.3) | Frame Shift Del (DEL) | VAF 55/129 reads (43%) | catalogued as rs781891121, COSV61745231; called by mutect2, varscan2
- POLR3E | c.838G>A p.D280N | Missense Mutation (SNP) | VAF 51/193 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as rs371071744, COSV55401592; called by muse, mutect2, varscan2
- POU2AF1 | c.253G>A p.A85T | Missense Mutation (SNP) | VAF 68/273 reads (25%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1313102269; called by muse, mutect2, varscan2
- PPCS | c.272C>T p.P91L | Missense Mutation (SNP) | VAF 84/279 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs267598605; called by muse, mutect2, varscan2
- PPIE | c.493G>A p.V165M | Missense Mutation (SNP) | VAF 39/177 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.971); catalogued as rs981534733, COSV60970948; called by muse, mutect2, varscan2
- PPP2R2B | c.1184T>G p.V395G (on ENST00000394409; = p.V461G on NM_181674.2) | Missense Mutation (SNP) | VAF 151/558 reads (27%) | SIFT tolerated (0.53); PolyPhen benign (0.001); catalogued as rs778098894, COSV60751353; called by muse, mutect2, varscan2
- PRAG1 | c.3359G>A p.R1120Q | Missense Mutation (SNP) | VAF 37/204 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs748634119, COSV58159065; called by muse, varscan2
- PRDM11 | c.779G>A p.S260N (on ENST00000530656 / NM_001359633.1; = p.S226N on NM_001256695.1) | Missense Mutation (SNP) | VAF 41/140 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs980724482; called by muse, mutect2, varscan2
- PRICKLE1 | c.2119G>A p.D707N | Missense Mutation (SNP) | VAF 149/570 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.053); catalogued as rs369077719; called by muse, mutect2, varscan2
- PRKAG2 | c.593del p.P198Rfs*56 | Frame Shift Del (DEL) | VAF 50/507 reads (10%) | catalogued as COSV55232567; called by mutect2, pindel
- PRMT5 | c.529G>A p.E177K | Missense Mutation (SNP) | VAF 68/272 reads (25%) | SIFT tolerated (0.6); PolyPhen benign (0.006); catalogued as rs568974453; called by muse, mutect2, varscan2
- PRMT7 | c.797G>A p.R266Q | Missense Mutation (SNP) | VAF 69/245 reads (28%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs756734451, COSV59833244; called by muse, mutect2, varscan2
- PROB1 | c.974G>A p.R325H | Missense Mutation (SNP) | VAF 53/172 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs1192257845; called by muse, mutect2, varscan2
- PROX1 | c.95C>T p.A32V | Missense Mutation (SNP) | VAF 48/168 reads (29%) | SIFT tolerated, low confidence (0.53); PolyPhen benign (0.001); catalogued as rs189248628; called by muse, mutect2, varscan2
- PRRG1 | c.5G>A p.G2E | Missense Mutation (SNP) | VAF 32/93 reads (34%) | SIFT tolerated (0.47); PolyPhen benign (0.003); catalogued as rs1227251752; called by muse, mutect2, varscan2
- PSD4 | c.1993C>T p.R665C | Missense Mutation (SNP) | VAF 14/58 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs141452297; called by muse, mutect2, varscan2
- PSMG2 | c.160C>T p.P54S | Missense Mutation (SNP) | VAF 62/261 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV50867868; called by muse, mutect2, varscan2
- PTCH2 | c.2642del p.P881Hfs*112 | Frame Shift Del (DEL) | VAF 54/247 reads (22%) | catalogued as rs1337855606; called by mutect2, pindel, varscan2
- PTPN3 | c.1105C>T p.P369S | Missense Mutation (SNP) | VAF 55/198 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs1281706002; called by muse, varscan2
- PTPRU | c.1916G>A p.R639Q | Missense Mutation (SNP) | VAF 66/231 reads (29%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.961); catalogued as rs1440930100, COSV60529287; called by muse, mutect2
- PUM1 | c.2863C>T p.R955W | Missense Mutation (SNP) | VAF 53/179 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.823); catalogued as rs773184181, COSV99928656; called by muse, mutect2, varscan2
- PZP | c.1406C>T p.T469M | Missense Mutation (SNP) | VAF 37/165 reads (22%) | SIFT tolerated (0.09); PolyPhen benign (0.298); catalogued as rs748511482, COSV54354857; called by muse, mutect2, varscan2
- QKI | c.731C>T p.P244L | Missense Mutation (SNP) | VAF 62/250 reads (25%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.786); catalogued as COSV51697919; called by muse, varscan2
- RADIL | c.2321del p.P774Hfs*98 | Frame Shift Del (DEL) | VAF 57/220 reads (26%) | catalogued as rs938303458; called by mutect2, pindel, varscan2
- RAMP3 | c.379G>A p.V127I | Missense Mutation (SNP) | VAF 102/357 reads (29%) | SIFT tolerated (0.24); PolyPhen benign (0.337); catalogued as rs778074274, COSV54246431; called by muse, mutect2, varscan2
- RAPGEF4 | c.2538del p.K846Nfs*5 | Frame Shift Del (DEL) | VAF 30/129 reads (23%) | catalogued as COSV51380239; called by mutect2, pindel, varscan2
- RASA3 | c.1370_1372del p.F457del | In Frame Del (DEL) | VAF 44/174 reads (25%) | catalogued as rs767949177; called by pindel, varscan2
- RASSF6 | c.478+2T>C p.X160_splice (on ENST00000342081 / NM_201431.2; = p.X128_splice on NM_177532.5) | Splice Site (SNP) | VAF 30/97 reads (31%) | catalogued as COSV100275113; called by muse, mutect2, varscan2
- RB1CC1 | c.1915C>G p.Q639E | Missense Mutation (SNP) | VAF 12/146 reads (8%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.122); catalogued as COSV99212256; called by muse, mutect2
- RDH14 | c.238_239dup p.E81Pfs*31 | Frame Shift Ins (INS) | VAF 30/106 reads (28%) | catalogued as rs985195122; called by mutect2, varscan2
- RELB | c.275del p.T92Rfs*23 | Frame Shift Del (DEL) | VAF 53/165 reads (32%) | catalogued as COSV55513078; called by mutect2, pindel, varscan2
- REV3L | c.7684C>A p.R2562S | Missense Mutation (SNP) | VAF 37/138 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100724744; called by muse, mutect2
- RHOXF1 | c.547G>A p.V183M | Missense Mutation (SNP) | VAF 46/123 reads (37%) | SIFT tolerated (0.2); PolyPhen benign (0.001); catalogued as rs782024712; called by muse, mutect2, varscan2
- RNF43 | c.1976del p.G659Vfs*41 | Frame Shift Del (DEL) | VAF 92/166 reads (55%) | catalogued as rs755128667, COSV68457540; called by mutect2, varscan2
- RPL22 | c.44del p.K15Rfs*5 | Frame Shift Del (DEL) | VAF 62/246 reads (25%) | catalogued as rs759765382, COSV52379423; called by mutect2, varscan2
- RPL6 | c.560G>A p.R187Q | Missense Mutation (SNP) | VAF 12/75 reads (16%) | SIFT tolerated (0.08); PolyPhen benign (0.316); catalogued as rs1484433336; called by muse, mutect2, varscan2
- RRP8 | c.1202G>A p.R401Q | Missense Mutation (SNP) | VAF 46/198 reads (23%) | SIFT tolerated (0.11); PolyPhen benign (0.009); catalogued as rs761872259, COSV54449007; called by muse, mutect2, varscan2
- RTL10 | c.445C>T p.R149* | Nonsense Mutation (SNP) | VAF 53/190 reads (28%) | catalogued as rs374166721; called by muse, mutect2, varscan2
- RUNX1T1 | c.1484G>A p.R495Q (on ENST00000265814 / NM_001198628.1; = p.R468Q on NM_004349.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 37/134 reads (28%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.851); catalogued as rs900545909, COSV56152742, COSV56166983; called by muse, mutect2, varscan2
- RUSC2 | c.1612C>T p.P538S | Missense Mutation (SNP) | VAF 59/169 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.722); catalogued as rs760106886; called by muse, mutect2, varscan2
- RYR1 | c.5054G>A p.C1685Y | Missense Mutation (SNP) | VAF 43/169 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs371686683; called by muse, mutect2, varscan2
- SAMD7 | c.1220A>T p.D407V | Missense Mutation (SNP) | VAF 43/165 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.577); catalogued as COSV59418356, COSV59419517; called by muse, mutect2, varscan2
- SART3 | c.1121G>A p.R374Q (on ENST00000228284; = p.R356Q on NM_014706.4) | Missense Mutation (SNP) | VAF 85/308 reads (28%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.642); catalogued as rs796086845, COSV99934570; called by muse, mutect2, varscan2
- SASS6 | c.170del p.L57Yfs*14 | Frame Shift Del (DEL) | VAF 22/121 reads (18%) | catalogued as rs763290832; called by mutect2, varscan2
- SCAF1 | c.2768C>T p.T923I | Missense Mutation (SNP) | VAF 22/57 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.086); catalogued as rs138632717; called by muse, mutect2, varscan2
- SCARA3 | c.1672T>G p.S558A | Missense Mutation (SNP) | VAF 18/69 reads (26%) | SIFT tolerated (0.74); PolyPhen benign (0); catalogued as rs756033244; called by muse, varscan2
- SCARA3 | c.1673C>A p.S558* | Nonsense Mutation (SNP) | VAF 18/68 reads (26%) | catalogued as rs777834810, COSV57271786; called by muse, varscan2
- SCN5A | c.5221dup p.D1741Gfs*48 (on ENST00000333535 / NM_198056.3; = p.D1740Gfs*48 on NM_000335.5) | Frame Shift Ins (INS) | VAF 86/363 reads (24%) | catalogued as rs1251085820; called by mutect2, pindel, varscan2
- SEC14L4 | c.230del p.P77Lfs*44 | Frame Shift Del (DEL) | VAF 25/133 reads (19%) | catalogued as rs1569243547; called by mutect2, pindel, varscan2
- SEC16A | c.6197del p.P2066Qfs*76 | Frame Shift Del (DEL) | VAF 41/157 reads (26%) | catalogued as COSV99256980; called by mutect2, pindel, varscan2
- SEPTIN12 | c.103G>A p.V35M | Missense Mutation (SNP) | VAF 82/272 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); catalogued as COSV99190857; called by muse, mutect2, varscan2
- SERPINE3 | c.524C>T p.P175L | Missense Mutation (SNP) | VAF 89/329 reads (27%) | SIFT tolerated (0.87); PolyPhen benign (0.003); catalogued as rs759208145, COSV68545429; called by muse, mutect2, varscan2
- SESTD1 | c.1709G>A p.R570H | Missense Mutation (SNP) | VAF 33/150 reads (22%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.976); catalogued as rs749484642, COSV100090882; called by muse, mutect2, varscan2
- SETD1B | c.5059G>T p.G1687C | Missense Mutation (SNP) | VAF 54/248 reads (22%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.98); catalogued as rs553963413; called by muse, mutect2, varscan2
- SETD2 | c.6706T>C p.S2236P | Missense Mutation (SNP) | VAF 52/190 reads (27%) | SIFT tolerated (0.05); PolyPhen benign (0.005); catalogued as rs1042427777, COSV100340412; called by muse, mutect2, varscan2
- SFMBT2 | c.391G>A p.V131M | Missense Mutation (SNP) | VAF 63/206 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1251850601, COSV62806679, COSV62813901; called by muse, mutect2, varscan2
- SH2D3C | c.877G>A p.V293M (on ENST00000314830 / NM_170600.3; = p.V136M on NM_005489.4) | Missense Mutation (SNP) | VAF 125/471 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); catalogued as rs982557076; called by muse, mutect2, varscan2
- SH3GLB2 | c.998del p.P333Lfs*? (on ENST00000372559; = p.P333Lfs*111 on NM_020145.4 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 71/242 reads (29%) | catalogued as rs780247761; called by pindel, varscan2
- SHFL | c.364C>T p.R122C | Missense Mutation (SNP) | VAF 52/162 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs372962161; called by muse, mutect2, varscan2
- SHROOM1 | c.884G>A p.G295D | Missense Mutation (SNP) | VAF 96/342 reads (28%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as rs139706949; called by muse, mutect2, varscan2
- SI | c.2482G>T p.G828* | Nonsense Mutation (SNP) | VAF 57/253 reads (23%) | catalogued as COSV52299032; called by muse, mutect2, varscan2
- SIN3B | c.2188C>T p.R730W | Missense Mutation (SNP) | VAF 58/213 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as rs756459568, COSV56136364; called by muse, mutect2, varscan2
- SIPA1L3 | c.4043G>A p.R1348H | Missense Mutation (SNP) | VAF 56/165 reads (34%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as rs143867865; called by muse, mutect2, varscan2
- SIVA1 | c.5C>A p.P2H | Missense Mutation (SNP) | VAF 63/214 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs11549005; called by muse, mutect2, varscan2
- SLC13A2 | c.322C>T p.R108C | Missense Mutation (SNP) | VAF 25/79 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs781925291; called by muse, mutect2, varscan2
- SLC1A5 | c.1426G>A p.A476T | Missense Mutation (SNP) | VAF 14/190 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs376590378, COSV69467326; called by muse, mutect2
- SLC25A37 | c.701C>T p.P234L | Missense Mutation (SNP) | VAF 44/144 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs777095457, COSV51563168, COSV51565626; called by muse, mutect2, varscan2
- SLC2A8 | c.1009G>A p.G337S | Missense Mutation (SNP) | VAF 46/138 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.975); catalogued as rs767430691, COSV64894485; called by muse, mutect2, varscan2
- SLC35G2 | c.192del p.R66Efs*18 | Frame Shift Del (DEL) | VAF 44/138 reads (32%) | catalogued as rs750825208; called by mutect2, varscan2
- SLC7A10 | c.471del p.T158Pfs*12 | Frame Shift Del (DEL) | VAF 43/116 reads (37%) | catalogued as rs753589038, COSV53507811; called by mutect2, varscan2
- SLCO2B1 | c.1982G>A p.G661D | Missense Mutation (SNP) | VAF 16/70 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs199644096; called by muse, mutect2, varscan2
- SLX4 | c.3722G>A p.R1241H | Missense Mutation (SNP) | VAF 72/280 reads (26%) | SIFT tolerated (0.19); PolyPhen benign (0.001); catalogued as rs773723496; called by muse, mutect2, varscan2
- SMCR8 | c.1853G>A p.R618H | Missense Mutation (SNP) | VAF 73/196 reads (37%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as rs751840133; called by muse, mutect2, varscan2
- SMTN | c.1605del p.S536Vfs*33 | Frame Shift Del (DEL) | VAF 14/64 reads (22%) | catalogued as rs758895137; called by mutect2, varscan2
- SNCB | c.401C>T p.A134V | Missense Mutation (SNP) | VAF 59/268 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.424); catalogued as rs189337482, COSV59527720; called by muse, mutect2, varscan2
- SND1 | c.2327G>A p.R776H | Missense Mutation (SNP) | VAF 109/376 reads (29%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.812); catalogued as rs139075193; called by muse, mutect2, varscan2
- SORCS2 | c.3163C>T p.R1055* | Nonsense Mutation (SNP) | VAF 20/103 reads (19%) | catalogued as rs768181356, COSV61170589; called by muse, mutect2, varscan2
- SOX7 | c.572del p.P191Rfs*80 | Frame Shift Del (DEL) | VAF 53/257 reads (21%) | catalogued as COSV58730928; called by mutect2, pindel, varscan2
- SPAM1 | c.404T>C p.M135T | Missense Mutation (SNP) | VAF 68/267 reads (25%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.636); catalogued as COSV56142816; called by muse, mutect2, varscan2
- SPHKAP | c.1411C>T p.P471S | Missense Mutation (SNP) | VAF 48/166 reads (29%) | SIFT tolerated (0.33); PolyPhen benign (0.01); catalogued as rs750450631; called by muse, mutect2, varscan2
- SPIN3 | c.560G>A p.R187H | Missense Mutation (SNP) | VAF 24/93 reads (26%) | SIFT tolerated (0.41); PolyPhen benign (0.014); catalogued as rs766002432, COSV66529335; called by muse, mutect2, varscan2
- SPTBN2 | c.774C>T p.D258= | Splice Region (SNP) | VAF 90/354 reads (25%) | catalogued as rs139240091; called by muse, mutect2, varscan2
- SRPK3 | c.1009G>A p.A337T | Missense Mutation (SNP) | VAF 43/96 reads (45%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as rs200511882; called by muse, mutect2, varscan2
- SRRM1 | c.110del p.K37Rfs*4 | Frame Shift Del (DEL) | VAF 25/98 reads (26%) | catalogued as COSV60481790; called by mutect2, pindel, varscan2
- SSC5D | c.589C>T p.R197W | Missense Mutation (SNP) | VAF 22/82 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.848); catalogued as rs773012015; called by muse, mutect2
- STARD13 | c.62C>A p.P21H | Missense Mutation (SNP) | VAF 51/209 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.733); catalogued as COSV60242335; called by muse, mutect2, varscan2
- SULF1 | c.1029del p.F343Lfs*7 | Frame Shift Del (DEL) | VAF 25/97 reads (26%) | catalogued as rs773014665, COSV52672549; called by mutect2, pindel, varscan2
- SULT6B1 | c.257del p.K86Sfs*21 (on ENST00000535679 / NM_001367551.1; = p.K48Sfs*21 on NM_001032377.2) | Frame Shift Del (DEL) | VAF 24/85 reads (28%) | catalogued as rs747003550; called by mutect2, varscan2
- SYCP1 | c.2642del p.K881Rfs*21 | Frame Shift Del (DEL) | VAF 10/52 reads (19%) | catalogued as rs776683356; called by mutect2, varscan2
- SYCP2 | c.2362del p.M788* | Frame Shift Del (DEL) | VAF 15/39 reads (38%) | catalogued as rs570102997; called by mutect2, varscan2
- SYNPO | c.290C>T p.A97V | Missense Mutation (SNP) | VAF 80/314 reads (25%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0); catalogued as rs763119227, COSV67784169; called by muse, varscan2
- SZT2 | c.4141C>T p.R1381* (on ENST00000634258 / NM_001365999.1; = p.R1324* on NM_015284.4) | Nonsense Mutation (SNP) | VAF 52/178 reads (29%) | catalogued as rs777424455, COSV65168036; called by muse, mutect2, varscan2
- TACC2 | c.2347del p.Q783Rfs*32 | Frame Shift Del (DEL) | VAF 57/240 reads (24%) | catalogued as rs750901207; called by mutect2, pindel, varscan2
- TACR2 | c.200T>C p.V67A | Missense Mutation (SNP) | VAF 47/186 reads (25%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.905); catalogued as COSV64822115; called by muse, mutect2, varscan2
- TBC1D10C | c.670G>A p.E224K | Missense Mutation (SNP) | VAF 30/119 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.051); catalogued as rs777317954, COSV56705036; called by muse, mutect2, varscan2
- TBC1D32 | c.3466-2dup p.X1156_splice | Splice Site (INS) | VAF 10/67 reads (15%) | catalogued as rs888646123; called by pindel, varscan2
- TBC1D5 | c.1492A>G p.R498G | Missense Mutation (SNP) | VAF 68/254 reads (27%) | SIFT tolerated (0.16); PolyPhen benign (0.006); catalogued as rs1447884004; called by muse, mutect2, varscan2
- TCEA1 | c.710G>A p.R237Q | Missense Mutation (SNP) | VAF 29/112 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs200499230; called by muse, mutect2, varscan2
- TET3 | c.2842C>T p.R948W | Missense Mutation (SNP) | VAF 58/207 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.797); catalogued as rs914916538; called by muse, mutect2, varscan2
- TFB2M | c.991C>T p.R331C | Missense Mutation (SNP) | VAF 61/233 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs200729611, COSV100830439; called by muse, mutect2, varscan2
- TFEB | c.739C>T p.R247* | Nonsense Mutation (SNP) | VAF 59/244 reads (24%) | catalogued as rs1323946945; called by muse, mutect2, varscan2
- TGOLN2 | c.1023_1025del p.E342del | In Frame Del (DEL) | VAF 96/402 reads (24%) | catalogued as rs1375730193; called by pindel, varscan2
- THBS3 | c.107C>T p.S36F | Missense Mutation (SNP) | VAF 102/303 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0.264); catalogued as rs759670617; called by muse, mutect2, varscan2
- TLE3 | c.1459del p.E487Rfs*6 | Frame Shift Del (DEL) | VAF 57/213 reads (27%) | catalogued as COSV100450229; called by mutect2, pindel, varscan2
- TLE3 | c.225G>A p.M75I | Missense Mutation (SNP) | VAF 34/135 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); catalogued as rs912580653; called by muse, mutect2, varscan2
- TLR2 | c.1039A>G p.K347E | Missense Mutation (SNP) | VAF 48/166 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.09); catalogued as rs779986684; called by muse, mutect2, varscan2
- TMEM119 | c.274C>T p.R92C | Missense Mutation (SNP) | VAF 83/343 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.804); catalogued as rs374738786; called by muse, mutect2, varscan2
- TMEM131 | c.3585del p.F1196Sfs*70 | Frame Shift Del (DEL) | VAF 26/86 reads (30%) | catalogued as COSV51778392; called by mutect2, pindel
- TMEM132C | c.1225C>T p.R409W | Missense Mutation (SNP) | VAF 33/147 reads (22%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.971); catalogued as rs368942654; called by muse, mutect2, varscan2
- TMEM35A | c.346G>A p.A116T | Missense Mutation (SNP) | VAF 78/173 reads (45%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.989); catalogued as COSV99516036; called by muse, mutect2, varscan2
- TNFRSF10B | c.533G>A p.C178Y | Missense Mutation (SNP) | VAF 63/218 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs147358455; called by muse, mutect2, varscan2
- TNFRSF4 | c.515del p.P172Qfs*? | Frame Shift Del (DEL) | VAF 65/228 reads (29%) | catalogued as rs769217131; called by mutect2, pindel, varscan2
- TNK1 | c.835A>G p.M279V | Missense Mutation (SNP) | VAF 23/71 reads (32%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.949); catalogued as rs1262146805; called by muse, mutect2, varscan2
- TNK2 | c.1482del p.D495Tfs*3 | Frame Shift Del (DEL) | VAF 17/44 reads (39%) | catalogued as rs750898925, COSV100361004; called by mutect2, pindel
- TONSL | c.3598G>A p.A1200T | Missense Mutation (SNP) | VAF 12/60 reads (20%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as rs369586558; called by muse, mutect2, varscan2
- TPH2 | c.1168G>A p.A390T | Missense Mutation (SNP) | VAF 80/350 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.536); catalogued as rs533065952, COSV100421965; called by muse, mutect2, varscan2
- TRIM36 | c.576A>G p.I192M | Missense Mutation (SNP) | VAF 54/187 reads (29%) | SIFT tolerated (0.14); PolyPhen benign (0.057); catalogued as COSV99143040; called by muse, mutect2, varscan2
- TRIM47 | c.1525G>A p.D509N | Missense Mutation (SNP) | VAF 95/275 reads (35%) | SIFT tolerated (0.41); PolyPhen benign (0.186); catalogued as rs200428444; called by muse, mutect2, varscan2
- TRPM2 | c.4027G>A p.G1343R | Missense Mutation (SNP) | VAF 52/182 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as rs760364925, COSV55974696; called by muse, mutect2, varscan2
- TSPOAP1 | c.917C>T p.A306V | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT tolerated (0.18); PolyPhen benign (0.022); catalogued as rs571682090; called by mutect2, varscan2
- TSTD2 | c.815del p.K272Rfs*20 | Frame Shift Del (DEL) | VAF 35/116 reads (30%) | catalogued as rs1457722181; called by mutect2, pindel, varscan2
- TTN | c.77404C>T p.R25802C (on ENST00000591111; = p.R18378C on NM_003319.4) | Missense Mutation (SNP) | VAF 57/206 reads (28%) | PolyPhen probably damaging (0.917); catalogued as rs755125180; called by muse, mutect2, varscan2
- TTN | c.56252G>A p.W18751* (on ENST00000591111; = p.W11327* on NM_003319.4) | Nonsense Mutation (SNP) | VAF 22/63 reads (35%) | catalogued as COSV60354946; called by muse, mutect2, varscan2
- TUBGCP3 | c.1145C>T p.A382V | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.932); catalogued as rs138653554; called by muse, mutect2, varscan2
- TXN2 | c.430G>A p.V144M | Missense Mutation (SNP) | VAF 50/243 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as rs775986664; called by muse, mutect2, varscan2
- UBB | c.114del p.D39Tfs*35 | Frame Shift Del (DEL) | VAF 108/462 reads (23%) | catalogued as rs1568883603; called by mutect2, pindel, varscan2
- UBE4B | c.3661G>A p.A1221T (on ENST00000343090 / NM_001105562.3; = p.A1092T on NM_006048.5) | Missense Mutation (SNP) | VAF 37/143 reads (26%) | SIFT tolerated (0.41); PolyPhen benign (0.069); catalogued as rs757353202, COSV53539719, COSV53543738; called by muse, mutect2, varscan2
- UBR5 | c.7713del p.F2571Lfs*4 | Frame Shift Del (DEL) | VAF 21/88 reads (24%) | catalogued as rs1471902646; called by mutect2, pindel, varscan2
- UCP1 | c.8del p.G3Afs*2 | Frame Shift Del (DEL) | VAF 60/243 reads (25%) | catalogued as rs538257429; called by mutect2, varscan2
- UGGT2 | c.2752G>A p.A918T | Missense Mutation (SNP) | VAF 25/110 reads (23%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as rs144777472; called by muse, mutect2, varscan2
- UNC13B | c.2104G>A p.E702K | Missense Mutation (SNP) | VAF 41/154 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as rs746321396, COSV65937892; called by muse, mutect2, varscan2
- UPF3B | c.971G>A p.R324H (on ENST00000276201 / NM_080632.3; = p.R311H on NM_023010.3) | Missense Mutation (SNP) | VAF 62/169 reads (37%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.869); catalogued as rs367608865, COSV52230750; called by muse, mutect2, varscan2
- UPF3B | c.23G>T p.R8M | Missense Mutation (SNP) | VAF 97/229 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.962); catalogued as COSV52230394; called by muse, mutect2, varscan2
- UVSSA | c.1856G>A p.R619H | Missense Mutation (SNP) | VAF 36/114 reads (32%) | SIFT tolerated (0.37); PolyPhen benign (0.003); catalogued as rs762934221; called by muse, mutect2, varscan2
- VEZT | c.220del p.S74Lfs*38 | Frame Shift Del (DEL) | VAF 27/119 reads (23%) | catalogued as rs748321397; called by mutect2, varscan2
- VPS41 | c.1163del p.N388Ifs*15 | Frame Shift Del (DEL) | VAF 45/139 reads (32%) | catalogued as rs757692785; called by mutect2, pindel, varscan2
- VPS51 | c.1828C>T p.R610W | Missense Mutation (SNP) | VAF 60/271 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54207970; called by muse, mutect2, varscan2
- VPS9D1 | c.947del p.P316Rfs*93 | Frame Shift Del (DEL) | VAF 8/51 reads (16%) | catalogued as rs1452701539; called by mutect2, pindel, varscan2
- WDFY4 | c.6899G>A p.R2300H | Missense Mutation (SNP) | VAF 58/243 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs537213971, COSV55443362; called by muse, mutect2, varscan2
- WDR24 | c.364G>A p.V122M (on ENST00000248142; = p.V60M on NM_032259.4) | Missense Mutation (SNP) | VAF 100/388 reads (26%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.793); catalogued as rs376830909; called by muse, mutect2, varscan2
- WDR49 | c.910G>T p.G304* (on ENST00000308378 / NM_001366158.1; = p.G645* on NM_001348951.2 and 2 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 24/80 reads (30%) | catalogued as COSV57706557; called by muse, mutect2, varscan2
- WDR6 | c.2333G>A p.R778H | Missense Mutation (SNP) | VAF 55/181 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs147897044; called by muse, mutect2, varscan2
- WDSUB1 | c.988G>A p.E330K | Missense Mutation (SNP) | VAF 22/330 reads (7%) | SIFT tolerated (0.34); PolyPhen benign (0.179); catalogued as rs199501078; called by muse, mutect2
- WDTC1 | c.868del p.E290Nfs*8 | Frame Shift Del (DEL) | VAF 39/136 reads (29%) | catalogued as rs747972901, COSV60089251; called by mutect2, varscan2
- WFDC5 | c.92C>T p.S31L | Missense Mutation (SNP) | VAF 47/151 reads (31%) | SIFT tolerated (0.69); PolyPhen benign (0.034); catalogued as rs551709664, COSV100332194; called by muse, mutect2, varscan2
- WIPI1 | c.193C>T p.R65C | Missense Mutation (SNP) | VAF 37/117 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs201800243, COSV50930483; called by muse, mutect2, varscan2
- WIZ | c.2627G>A p.R876Q (on ENST00000673675 / NM_001371589.1; = p.R139Q on NM_021241.3) | Missense Mutation (SNP) | VAF 46/132 reads (35%) | SIFT tolerated (0.25); PolyPhen benign (0.04); catalogued as rs376481490; called by muse, mutect2, varscan2
- WNT5B | c.332G>A p.S111N | Missense Mutation (SNP) | VAF 32/101 reads (32%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.9); catalogued as COSV60198240; called by muse, mutect2, varscan2
- WNT9A | c.500del p.G167Afs*38 | Frame Shift Del (DEL) | VAF 70/246 reads (28%) | catalogued as rs779992922; called by mutect2, varscan2
- XYLT1 | c.2080C>T p.R694C | Missense Mutation (SNP) | VAF 54/179 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as rs770765433; called by muse, mutect2, varscan2
- YWHAE | c.43G>A p.E15K | Missense Mutation (SNP) | VAF 90/313 reads (29%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.233); catalogued as COSV51983240, COSV51984459; called by muse, varscan2
- ZAN | c.347G>A p.C116Y | Missense Mutation (SNP) | VAF 143/454 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs768485420; called by muse, mutect2, varscan2
- ZBTB16 | c.1573C>A p.R525S | Missense Mutation (SNP) | VAF 144/602 reads (24%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as COSV60098584; called by muse, mutect2, varscan2
- ZBTB7C | c.394del p.D132Tfs*90 | Frame Shift Del (DEL) | VAF 57/162 reads (35%) | catalogued as COSV59691020; called by mutect2, varscan2
- ZCCHC7 | c.674G>A p.R225Q | Missense Mutation (SNP) | VAF 32/123 reads (26%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.743); catalogued as rs761303878, COSV60961837; called by muse, varscan2
- ZCRB1 | c.419dup p.K141Efs*4 | Frame Shift Ins (INS) | VAF 38/135 reads (28%) | catalogued as rs750821771; called by mutect2, varscan2
- ZEB1 | c.2747G>T p.S916I | Missense Mutation (SNP) | VAF 70/245 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs750075928; called by muse, mutect2, varscan2
- ZEB2 | c.1426del p.M476Wfs*11 | Frame Shift Del (DEL) | VAF 35/117 reads (30%) | catalogued as CD052131; called by mutect2, pindel, varscan2
- ZFHX3 | c.10215del p.A3407Lfs*78 | Frame Shift Del (DEL) | VAF 25/126 reads (20%) | catalogued as rs762108866; called by pindel, varscan2
- ZFHX3 | c.2756del p.G919Afs*9 | Frame Shift Del (DEL) | VAF 29/121 reads (24%) | catalogued as COSV51712047; called by mutect2, pindel, varscan2
- ZFHX4 | c.523G>C p.E175Q | Missense Mutation (SNP) | VAF 45/173 reads (26%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.623); catalogued as COSV99268141; called by muse, mutect2, varscan2
- ZFP42 | c.905C>T p.T302M | Missense Mutation (SNP) | VAF 20/77 reads (26%) | SIFT tolerated (0.08); PolyPhen benign (0.226); catalogued as rs1002401560; called by muse, mutect2
- ZMYND8 | c.1511C>T p.T504M (on ENST00000311275 / NM_001363741.2; = p.T524M on NM_012408.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 54/235 reads (23%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.075); catalogued as rs61756442; called by muse, mutect2, varscan2
- ZNF121 | c.964G>A p.A322T | Missense Mutation (SNP) | VAF 36/132 reads (27%) | SIFT tolerated (0.75); PolyPhen benign (0.017); catalogued as rs1488017927; called by muse, mutect2, varscan2
- ZNF217 | c.2497G>A p.A833T | Missense Mutation (SNP) | VAF 71/246 reads (29%) | SIFT tolerated (0.75); PolyPhen benign (0.001); catalogued as rs886220026, COSV100184702; called by muse, mutect2, varscan2
- ZNF324B | c.1451C>T p.T484M | Missense Mutation (SNP) | VAF 68/244 reads (28%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.91); catalogued as rs762582025, COSV60741475; called by muse, mutect2, varscan2
- ZNF517 | c.1364G>A p.R455H | Missense Mutation (SNP) | VAF 15/57 reads (26%) | SIFT tolerated (0.15); PolyPhen benign (0.001); catalogued as rs770935296, COSV100743350; called by muse, mutect2, varscan2
- ZNF524 | c.214del p.V72* | Frame Shift Del (DEL) | VAF 28/102 reads (27%) | catalogued as rs1249713061; called by mutect2, varscan2
- ZNF570 | c.233_234del p.E78Afs*14 | Frame Shift Del (DEL) | VAF 26/134 reads (19%) | catalogued as rs756485651; called by pindel, varscan2
- ZNF592 | c.2812C>T p.P938S | Missense Mutation (SNP) | VAF 17/215 reads (8%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as COSV100246123; called by muse, mutect2
- ZNF627 | c.318_319dup p.G107Vfs*43 | Frame Shift Ins (INS) | VAF 36/164 reads (22%) | catalogued as rs767290608; called by mutect2, varscan2
- ZNF668 | c.1186G>A p.A396T | Missense Mutation (SNP) | VAF 80/222 reads (36%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.598); catalogued as rs749330382, COSV100336575; called by muse, mutect2, varscan2
- ZNF821 | c.77G>A p.R26H | Missense Mutation (SNP) | VAF 34/123 reads (28%) | SIFT tolerated, low confidence (0.3); PolyPhen probably damaging (0.964); catalogued as rs769813579, COSV57987633; called by muse, mutect2, varscan2
- ZNF835 | c.1019C>T p.A340V | Missense Mutation (SNP) | VAF 55/212 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.21); catalogued as COSV73379263; called by muse, varscan2
- ZNF835 | c.907G>A p.E303K | Missense Mutation (SNP) | VAF 70/278 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV101606435, COSV73379772; called by muse, varscan2
- ZNHIT6 | c.941G>A p.R314Q | Missense Mutation (SNP) | VAF 24/149 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.944); catalogued as rs542482220; called by muse, mutect2, varscan2
- ZXDC | c.2435G>A p.G812D | Missense Mutation (SNP) | VAF 36/171 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.001); catalogued as COSV100729118; called by muse, mutect2, varscan2
- AATK | c.1415G>A p.S472N (on ENST00000326724 / NM_001080395.3; = p.S369N on NM_004920.2) | Missense Mutation (SNP) | VAF 42/117 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- ABCA7 | c.5900G>T p.S1967I | Missense Mutation (SNP) | VAF 18/76 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.01); called by muse, varscan2
- ABCG8 | c.829T>A p.F277I | Missense Mutation (SNP) | VAF 84/347 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ABO | c.801del p.F268Sfs*20 | Frame Shift Del (DEL) | VAF 110/446 reads (25%) | called by mutect2, pindel, varscan2
- AC092143.1 | c.1858del p.L620Sfs*12 | Frame Shift Del (DEL) | VAF 193/737 reads (26%) | called by mutect2, pindel, varscan2
- AC245033.1 | c.1572G>T p.E524D | Missense Mutation (SNP) | VAF 58/657 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.099); called by muse, mutect2
- ACOXL | c.903C>T p.S301= | Splice Region (SNP) | VAF 25/80 reads (31%) | called by muse, mutect2, varscan2
- ACRBP | c.828G>C p.E276D | Missense Mutation (SNP) | VAF 48/162 reads (30%) | SIFT tolerated (0.52); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ACSF3 | c.974T>A p.I325N | Missense Mutation (SNP) | VAF 76/286 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- ACTN2 | c.1672C>T p.H558Y | Missense Mutation (SNP) | VAF 79/296 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- ADAM11 | c.268A>G p.I90V | Missense Mutation (SNP) | VAF 37/165 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- ADAMTS13 | c.2848C>A p.P950T | Missense Mutation (SNP) | VAF 118/356 reads (33%) | SIFT tolerated (0.1); PolyPhen benign (0.245); called by muse, mutect2, varscan2
- ADGRA2 | c.734T>C p.L245P | Missense Mutation (SNP) | VAF 8/166 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- ADRA1A | c.477dup p.G160Wfs*141 | Frame Shift Ins (INS) | VAF 59/257 reads (23%) | called by mutect2, pindel, varscan2
- AGAP5 | c.1226A>G p.N409S | Missense Mutation (SNP) | VAF 60/1102 reads (5%) | SIFT tolerated (0.48); PolyPhen probably damaging (0.973); called by muse, mutect2
- AGL | c.2965C>T p.Q989* | Nonsense Mutation (SNP) | VAF 72/294 reads (24%) | called by muse, mutect2, varscan2
- AGO2 | c.1492del p.A498Rfs*11 | Frame Shift Del (DEL) | VAF 15/133 reads (11%) | called by mutect2, pindel, varscan2
- AKT3 | c.995T>C p.L332P | Missense Mutation (SNP) | VAF 51/189 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- AL441992.2 | c.1420G>A p.V474I | Missense Mutation (SNP) | VAF 22/114 reads (19%) | SIFT tolerated (0.15); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ALAS1 | c.1619dup p.N540Kfs*6 | Frame Shift Ins (INS) | VAF 35/119 reads (29%) | called by mutect2, pindel, varscan2
- ALDH16A1 | c.1224del p.F409Sfs*93 | Frame Shift Del (DEL) | VAF 32/110 reads (29%) | called by mutect2, varscan2
- ALDH2 | c.38G>A p.G13D | Missense Mutation (SNP) | VAF 68/216 reads (31%) | SIFT tolerated (0.14); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- ANAPC5 | c.958G>A p.A320T | Missense Mutation (SNP) | VAF 23/101 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ANK3 | c.12059del p.K4020Rfs*45 | Frame Shift Del (DEL) | VAF 80/238 reads (34%) | called by mutect2, pindel, varscan2
- ANKHD1-EIF4EBP3 | c.7279C>T p.Q2427* | Nonsense Mutation (SNP) | VAF 51/171 reads (30%) | called by muse, mutect2, varscan2
- ANKRD18A | c.1199G>T p.R400M | Missense Mutation (SNP) | VAF 35/117 reads (30%) | SIFT tolerated (0.78); PolyPhen benign (0); called by muse, mutect2, varscan2
- ANKRD30B | c.800del p.N267Ifs*74 | Frame Shift Del (DEL) | VAF 38/168 reads (23%) | called by pindel, varscan2
- ANO2 | c.2552del p.F851Sfs*6 (on ENST00000356134 / NM_001278597.3; = p.F855Sfs*6 on NM_001278596.3) | Frame Shift Del (DEL) | VAF 53/197 reads (27%) | called by mutect2, pindel, varscan2
- AP000812.4 | c.299C>T p.T100I | Missense Mutation (SNP) | VAF 23/74 reads (31%) | SIFT tolerated (0.09); PolyPhen benign (0.076); called by muse, mutect2, varscan2
- APOL1 | c.566T>C p.L189P | Missense Mutation (SNP) | VAF 25/85 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- AQR | c.1556T>C p.V519A | Missense Mutation (SNP) | VAF 69/257 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.64); called by muse, mutect2, varscan2
- ARFGAP1 | c.287G>A p.C96Y | Missense Mutation (SNP) | VAF 18/74 reads (24%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.464); called by muse, mutect2, varscan2
- ARHGAP5 | c.2805del p.F935Lfs*5 | Frame Shift Del (DEL) | VAF 14/116 reads (12%) | called by mutect2, pindel
- ARHGEF40 | c.3332del p.P1111Lfs*5 | Frame Shift Del (DEL) | VAF 28/96 reads (29%) | called by mutect2, pindel, varscan2
- ARID1B | c.2268del p.S758Afs*11 | Frame Shift Del (DEL) | VAF 49/261 reads (19%) | called by mutect2, pindel, varscan2
- ARID1B | c.4150A>G p.S1384G | Missense Mutation (SNP) | VAF 17/202 reads (8%) | SIFT tolerated (0.96); PolyPhen benign (0); called by muse, mutect2
- ARID4A | c.1584del p.E529Rfs*46 | Frame Shift Del (DEL) | VAF 48/199 reads (24%) | called by mutect2, pindel, varscan2
- ARMCX2 | c.1792del p.Y598Tfs*16 | Frame Shift Del (DEL) | VAF 19/55 reads (35%) | called by mutect2, pindel
- ARPP21 | c.1459+5G>T | Splice Region (SNP) | VAF 35/123 reads (28%) | called by muse, varscan2
- ASAP1 | c.1909G>T p.G637* | Nonsense Mutation (SNP) | VAF 32/142 reads (23%) | called by muse, varscan2
- ASAP1 | c.320del p.L107* | Frame Shift Del (DEL) | VAF 28/130 reads (22%) | called by mutect2, pindel, varscan2
- ASAP2 | c.2357del p.P786Rfs*25 | Frame Shift Del (DEL) | VAF 37/132 reads (28%) | called by mutect2, pindel, varscan2
- ATAD2B | c.2446T>C p.C816R | Missense Mutation (SNP) | VAF 19/74 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ATAD3A | c.528+1G>A p.X176_splice | Splice Site (SNP) | VAF 51/178 reads (29%) | called by muse, mutect2, varscan2
- ATF3 | c.251A>G p.E84G | Missense Mutation (SNP) | VAF 107/397 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.31); called by muse, mutect2, varscan2
- ATP13A3 | c.2810G>C p.C937S | Missense Mutation (SNP) | VAF 26/147 reads (18%) | SIFT deleterious (0.05); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- ATP1A2 | c.1981G>A p.V661M | Missense Mutation (SNP) | VAF 124/479 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ATP5MD | c.154del p.T52Lfs*4 | Frame Shift Del (DEL) | VAF 37/143 reads (26%) | called by mutect2, pindel, varscan2
- ATP7B | c.323G>A p.C108Y | Missense Mutation (SNP) | VAF 222/814 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- BAZ1B | c.1984C>A p.L662I | Missense Mutation (SNP) | VAF 46/171 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- BAZ2A | c.2840C>T p.A947V | Missense Mutation (SNP) | VAF 62/254 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.815); called by muse, mutect2, varscan2
- BIK | c.440T>C p.L147P | Missense Mutation (SNP) | VAF 60/228 reads (26%) | SIFT tolerated, low confidence (0.17); PolyPhen probably damaging (0.993); called by muse, varscan2
- BIN1 | c.1123C>A p.P375T | Missense Mutation (SNP) | VAF 17/51 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- BPTF | c.8154del p.K2718Nfs*36 | Frame Shift Del (DEL) | VAF 72/288 reads (25%) | called by mutect2, varscan2
- BRDT | c.215dup p.N72Kfs*9 | Frame Shift Ins (INS) | VAF 12/60 reads (20%) | called by mutect2, pindel, varscan2
- BRF1 | c.876del p.S293Rfs*11 | Frame Shift Del (DEL) | VAF 67/238 reads (28%) | called by mutect2, varscan2
- C14orf28 | c.474G>A p.W158* | Nonsense Mutation (SNP) | VAF 27/80 reads (34%) | called by muse, mutect2, varscan2
- C15orf39 | c.1650del p.T551Pfs*14 | Frame Shift Del (DEL) | VAF 18/59 reads (31%) | called by mutect2, pindel, varscan2
- C16orf96 | c.1302G>A p.W434* | Nonsense Mutation (SNP) | VAF 30/86 reads (35%) | called by muse, mutect2, varscan2
- C16orf96 | c.1355C>T p.A452V | Missense Mutation (SNP) | VAF 44/164 reads (27%) | SIFT tolerated (0.08); PolyPhen benign (0.01); called by muse, varscan2
- C1QTNF12 | c.433del p.A145Rfs*46 | Frame Shift Del (DEL) | VAF 25/92 reads (27%) | called by pindel, varscan2
- C1RL | c.1051del p.L351Wfs*35 | Frame Shift Del (DEL) | VAF 23/73 reads (32%) | called by mutect2, pindel, varscan2
- C2CD3 | c.949_951del p.L317del | In Frame Del (DEL) | VAF 30/120 reads (25%) | called by pindel, varscan2
- C3 | c.52C>A p.P18T | Missense Mutation (SNP) | VAF 37/179 reads (21%) | SIFT tolerated (0.09); PolyPhen benign (0.133); called by muse, mutect2, varscan2
- C6 | c.1525A>G p.K509E | Missense Mutation (SNP) | VAF 103/444 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.527); called by muse, mutect2, varscan2
- CA4 | c.820C>T p.Q274* | Nonsense Mutation (SNP) | VAF 100/324 reads (31%) | called by muse, mutect2, varscan2
- CABS1 | c.116C>T p.T39I | Missense Mutation (SNP) | VAF 39/191 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.372); called by muse, mutect2, varscan2
- CACNA1F | c.3913A>G p.K1305E | Missense Mutation (SNP) | VAF 18/205 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- CACNA1F | c.351G>T p.E117D | Missense Mutation (SNP) | VAF 88/227 reads (39%) | SIFT tolerated (0.09); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- CAD | c.5974C>T p.L1992F | Missense Mutation (SNP) | VAF 78/310 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.624); called by muse, mutect2, varscan2
- CAPN14 | c.618_619insT p.G207Wfs*63 | Frame Shift Ins (INS) | VAF 40/168 reads (24%) | called by pindel, varscan2
- CASR | c.2499del p.S834Pfs*28 (on ENST00000490131; = p.S911Pfs*28 on NM_000388.4) | Frame Shift Del (DEL) | VAF 28/132 reads (21%) | called by mutect2, pindel, varscan2
- CBLIF | c.370+8C>T | Splice Region (SNP) | VAF 93/385 reads (24%) | called by muse, mutect2, varscan2
- CCDC17 | c.1856del p.P619Qfs*2 | Frame Shift Del (DEL) | VAF 25/159 reads (16%) | called by mutect2, pindel, varscan2
- CCDC66 | c.2234del p.N745Ifs*28 (on ENST00000394672 / NM_001353147.1; = p.N711Ifs*28 on NM_001012506.5 and 6 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 61/274 reads (22%) | called by mutect2, pindel, varscan2
- CCDC74B | c.796C>A p.L266M | Missense Mutation (SNP) | VAF 50/216 reads (23%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CCIN | c.616T>C p.Y206H | Missense Mutation (SNP) | VAF 92/372 reads (25%) | SIFT tolerated (0.14); PolyPhen benign (0); called by muse, mutect2, varscan2
- CCNQ | c.179G>A p.C60Y | Missense Mutation (SNP) | VAF 114/275 reads (41%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.447); called by muse, mutect2, varscan2
- CD68 | c.64A>G p.N22D | Missense Mutation (SNP) | VAF 12/122 reads (10%) | SIFT tolerated (0.16); PolyPhen benign (0); called by muse, mutect2
- CD79A | c.390del p.R131Gfs*61 | Frame Shift Del (DEL) | VAF 33/115 reads (29%) | called by mutect2, pindel, varscan2
- CDAN1 | c.3025del p.E1009Sfs*23 | Frame Shift Del (DEL) | VAF 8/36 reads (22%) | called by mutect2, pindel, varscan2
- CDC34 | c.40C>A p.L14M | Missense Mutation (SNP) | VAF 22/71 reads (31%) | SIFT tolerated (0.6); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- CDC7 | c.599C>T p.A200V | Missense Mutation (SNP) | VAF 40/134 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- CDCA2 | c.2336G>A p.C779Y | Missense Mutation (SNP) | VAF 64/214 reads (30%) | SIFT tolerated (0.23); PolyPhen benign (0.159); called by muse, varscan2
- CDCA2 | c.2348T>C p.M783T | Missense Mutation (SNP) | VAF 58/208 reads (28%) | SIFT tolerated (0.52); PolyPhen benign (0.007); called by muse, varscan2
- CDCA5 | c.150G>T p.L50F | Missense Mutation (SNP) | VAF 41/162 reads (25%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.131); called by muse, mutect2, varscan2
- CDH16 | c.31G>A p.V11I | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT tolerated (0.18); PolyPhen benign (0); called by muse, mutect2, varscan2
- CDH23 | c.494del p.G165Afs*25 | Frame Shift Del (DEL) | VAF 20/91 reads (22%) | called by mutect2, pindel, varscan2
- CDKL4 | c.391A>G p.N131D | Missense Mutation (SNP) | VAF 29/124 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CENPT | c.1046C>T p.A349V | Missense Mutation (SNP) | VAF 44/516 reads (9%) | SIFT tolerated (0.24); PolyPhen benign (0.031); called by muse, mutect2
- CFAP43 | c.3333+2C>T p.X1111_splice | Splice Site (SNP) | VAF 53/150 reads (35%) | called by muse, mutect2, varscan2
- CHD2 | c.4183_4185del p.K1395del | In Frame Del (DEL) | VAF 30/129 reads (23%) | called by mutect2, pindel, varscan2
- CHD3 | c.5002del p.E1668Kfs*11 (on ENST00000330494 / NM_001005273.3; = p.E1727Kfs*11 on NM_001005271.3) | Frame Shift Del (DEL) | VAF 4/44 reads (9%) | called by mutect2, pindel
- CHD7 | c.3436A>G p.S1146G | Missense Mutation (SNP) | VAF 10/152 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.739); called by muse, mutect2
- CHPF | c.532C>T p.H178Y | Missense Mutation (SNP) | VAF 61/252 reads (24%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- CHRNA7 | c.703C>A p.L235I | Missense Mutation (SNP) | VAF 24/478 reads (5%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.467); called by muse, mutect2
- CIT | c.4820T>C p.V1607A | Missense Mutation (SNP) | VAF 40/123 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.524); called by muse, mutect2, varscan2
- CLIP2 | c.2878C>T p.L960= | Splice Region (SNP) | VAF 29/115 reads (25%) | called by muse, mutect2, varscan2
- CLN8 | c.55G>A p.A19T | Missense Mutation (SNP) | VAF 62/219 reads (28%) | SIFT tolerated (0.51); PolyPhen benign (0); called by muse, mutect2, varscan2
- CLNS1A | c.263-1G>A p.X88_splice | Splice Site (SNP) | VAF 40/109 reads (37%) | called by muse, mutect2, varscan2
- CNBD2 | c.608T>C p.V203A | Missense Mutation (SNP) | VAF 60/171 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.615); called by muse, mutect2, varscan2
- COL4A2 | c.4862T>A p.I1621N | Missense Mutation (SNP) | VAF 42/148 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, varscan2
- COL4A3 | c.4483C>T p.Q1495* | Nonsense Mutation (SNP) | VAF 86/338 reads (25%) | called by muse, mutect2, varscan2
- COL6A3 | c.4811dup p.N1604Kfs*61 | Frame Shift Ins (INS) | VAF 51/216 reads (24%) | called by pindel, varscan2
- COL6A5 | c.4259A>G p.H1420R | Missense Mutation (SNP) | VAF 24/132 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.989); called by muse, varscan2
- COPG1 | c.52C>A p.P18T | Missense Mutation (SNP) | VAF 40/148 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- CORO1B | c.493G>A p.A165T | Missense Mutation (SNP) | VAF 40/151 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CRIM1 | c.1360C>T p.P454S | Missense Mutation (SNP) | VAF 91/285 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CROCC2 | c.1166del p.P389Hfs*21 | Frame Shift Del (DEL) | VAF 24/74 reads (32%) | called by mutect2, pindel, varscan2
- CSMD3 | c.3311-2A>T p.X1104_splice (on ENST00000297405 / NM_001363185.1; = p.X1000_splice on NM_052900.3) | Splice Site (SNP) | VAF 51/200 reads (26%) | called by muse, mutect2, varscan2
- CTPS1 | c.641T>G p.V214G | Missense Mutation (SNP) | VAF 41/164 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.609); called by muse, varscan2
- CYFIP1 | c.3144_3145del p.R1049Tfs*15 | Frame Shift Del (DEL) | VAF 23/102 reads (23%) | called by mutect2, pindel, varscan2
- CYP4F11 | c.192G>T p.Q64H | Missense Mutation (SNP) | VAF 32/142 reads (23%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.704); called by muse, mutect2, varscan2
- DAZAP1 | c.1124del p.G375Vfs*54 | Frame Shift Del (DEL) | VAF 44/151 reads (29%) | called by mutect2, varscan2
- DDX54 | c.1897C>T p.P633S | Missense Mutation (SNP) | VAF 43/169 reads (25%) | SIFT tolerated (0.61); PolyPhen benign (0.053); called by muse, mutect2, varscan2
- DEPDC1 | c.359C>T p.P120L | Missense Mutation (SNP) | VAF 34/131 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.035); called by muse, varscan2
- DHX9 | c.3193del p.L1065Cfs*20 | Frame Shift Del (DEL) | VAF 43/205 reads (21%) | called by mutect2, pindel, varscan2
- DIRAS1 | c.160G>A p.V54M | Missense Mutation (SNP) | VAF 39/172 reads (23%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.914); called by muse, mutect2, varscan2
- DLEU7 | c.321del p.C110Afs*43 | Frame Shift Del (DEL) | VAF 12/62 reads (19%) | called by mutect2, pindel
- DNAH1 | c.12767G>A p.G4256D | Missense Mutation (SNP) | VAF 42/191 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DNAH17 | c.7528G>A p.G2510R | Missense Mutation (SNP) | VAF 42/126 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DNHD1 | c.12449A>G p.H4150R | Missense Mutation (SNP) | VAF 43/166 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.123); called by muse, mutect2, varscan2
- DNHD1 | c.13394A>G p.E4465G | Missense Mutation (SNP) | VAF 8/176 reads (5%) | SIFT tolerated (0.11); PolyPhen benign (0.144); called by muse, mutect2
- DNMT1 | c.2373G>A p.M791I | Missense Mutation (SNP) | VAF 112/410 reads (27%) | SIFT tolerated (0.07); PolyPhen benign (0.261); called by muse, mutect2, varscan2
- DOCK6 | c.5861del p.L1954* | Frame Shift Del (DEL) | VAF 30/125 reads (24%) | called by mutect2, pindel, varscan2
- DOCK7 | c.886-3dup | Splice Region (INS) | VAF 28/118 reads (24%) | called by mutect2, pindel
- DPP9 | c.1303G>A p.G435R (on ENST00000598800; = p.G464R on NM_139159.5) | Missense Mutation (SNP) | VAF 20/236 reads (8%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.994); called by muse, mutect2
- DRC7 | c.1077+8G>T | Splice Region (SNP) | VAF 100/355 reads (28%) | called by muse, mutect2, varscan2
- DST | c.1480C>T p.Q494* (on ENST00000361203 / NM_001374722.1; = p.Q168* on NM_001723.6) | Nonsense Mutation (SNP) | VAF 63/235 reads (27%) | called by muse, mutect2, varscan2
- DTNB | c.242T>C p.L81P | Missense Mutation (SNP) | VAF 30/444 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- DUSP9 | c.34C>T p.R12C | Missense Mutation (SNP) | VAF 27/65 reads (42%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.828); called by muse, mutect2, varscan2
- DYNC2H1 | c.8283del p.F2761Lfs*20 | Frame Shift Del (DEL) | VAF 20/94 reads (21%) | called by mutect2, varscan2
- DYRK1B | c.857T>C p.L286P | Missense Mutation (SNP) | VAF 51/179 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DYRK3 | c.697C>T p.Q233* | Nonsense Mutation (SNP) | VAF 45/207 reads (22%) | called by muse, mutect2, varscan2
- EBF1 | c.1219A>G p.I407V | Missense Mutation (SNP) | VAF 20/56 reads (36%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0); called by muse, mutect2, varscan2
- ECEL1 | c.80dup p.A28Rfs*74 | Frame Shift Ins (INS) | VAF 32/105 reads (30%) | called by mutect2, pindel, varscan2
- ECSIT | c.781del p.Q261Sfs*5 | Frame Shift Del (DEL) | VAF 80/312 reads (26%) | called by mutect2, varscan2
- EDEM3 | c.1103C>T p.A368V | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by mutect2, varscan2
- EDNRB | c.1187G>A p.G396D (on ENST00000377211 / NM_001201397.1; = p.G306D on NM_000115.5) | Missense Mutation (SNP) | VAF 80/302 reads (26%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.642); called by muse, mutect2, varscan2
- EIF3J | c.180del p.E61Rfs*5 | Frame Shift Del (DEL) | VAF 19/108 reads (18%) | called by mutect2, varscan2
- ELMO1 | c.212del p.N71Mfs*7 | Frame Shift Del (DEL) | VAF 36/194 reads (19%) | called by mutect2, pindel, varscan2
- ENO3 | c.23C>T p.A8V | Missense Mutation (SNP) | VAF 30/558 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.985); called by muse, mutect2
- EPB41L4B | c.883G>T p.G295C | Missense Mutation (SNP) | VAF 9/186 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2
- EPHX4 | c.47G>A p.R16Q | Missense Mutation (SNP) | VAF 43/189 reads (23%) | SIFT tolerated (0.56); PolyPhen benign (0.278); called by muse, mutect2, varscan2
- ERBB4 | c.2387C>A p.T796N | Missense Mutation (SNP) | VAF 68/251 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ERCC6 | c.1517del p.K506Sfs*37 | Frame Shift Del (DEL) | VAF 83/292 reads (28%) | called by mutect2, pindel, varscan2
- ERG | c.188G>A p.W63* | Nonsense Mutation (SNP) | VAF 78/296 reads (26%) | called by muse, mutect2, varscan2
- ERVV-1 | c.915del p.I306* | Frame Shift Del (DEL) | VAF 32/134 reads (24%) | called by mutect2, varscan2
- ESM1 | c.305G>A p.C102Y | Missense Mutation (SNP) | VAF 45/150 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- EXOC7 | c.1439C>T p.A480V (on ENST00000335146 / NM_001145297.4; = p.A398V on NM_015219.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 63/210 reads (30%) | SIFT tolerated (0.48); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- EXOSC10 | c.1697T>A p.I566N | Missense Mutation (SNP) | VAF 45/183 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.71); called by muse, mutect2, varscan2
- FADS1 | c.988G>A p.A330T | Missense Mutation (SNP) | VAF 26/152 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.16); called by muse, mutect2, varscan2
- FAM120B | c.1532G>A p.C511Y | Missense Mutation (SNP) | VAF 61/192 reads (32%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- FAM168B | c.61G>T p.G21C | Missense Mutation (SNP) | VAF 42/155 reads (27%) | SIFT tolerated, low confidence (0.06); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FASN | c.313_314del p.T105Wfs*10 | Frame Shift Del (DEL) | VAF 126/423 reads (30%) | called by pindel, varscan2
- FAT2 | c.12892del p.V4298Wfs*98 | Frame Shift Del (DEL) | VAF 75/263 reads (29%) | called by mutect2, pindel, varscan2
- FAT3 | c.12742A>G p.N4248D | Missense Mutation (SNP) | VAF 17/286 reads (6%) | SIFT tolerated (0.06); PolyPhen benign (0.236); called by muse, mutect2
- FBL | c.951del p.K318Rfs*2 | Frame Shift Del (DEL) | VAF 36/132 reads (27%) | called by mutect2, pindel, varscan2
- FBXO16 | c.869+2T>C p.X290_splice | Splice Site (SNP) | VAF 49/223 reads (22%) | called by muse, mutect2, varscan2
- FBXO21 | c.505del p.I169Ffs*11 | Frame Shift Del (DEL) | VAF 40/159 reads (25%) | called by mutect2, varscan2
- FBXO43 | c.1649T>C p.I550T | Missense Mutation (SNP) | VAF 27/103 reads (26%) | SIFT deleterious (0.05); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- FER | c.1428del p.K476Nfs*53 | Frame Shift Del (DEL) | VAF 64/236 reads (27%) | called by pindel, varscan2
- FGFR1 | c.2047G>A p.V683M (on ENST00000447712 / NM_023110.3; = p.V681M on NM_015850.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 118/473 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FHOD3 | c.1004_1005del p.P335Qfs*63 | Frame Shift Del (DEL) | VAF 13/35 reads (37%) | called by mutect2, pindel, varscan2
- FLG2 | c.4673A>G p.H1558R | Missense Mutation (SNP) | VAF 65/216 reads (30%) | SIFT tolerated (0.15); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- FLG2 | c.3106T>C p.S1036P | Missense Mutation (SNP) | VAF 30/584 reads (5%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.831); called by muse, mutect2
- FLI1 | c.461T>G p.I154S | Missense Mutation (SNP) | VAF 39/218 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.178); called by muse, mutect2, varscan2
- FMR1 | c.542C>T p.A181V | Missense Mutation (SNP) | VAF 79/258 reads (31%) | SIFT tolerated (0.2); PolyPhen benign (0.109); called by muse, mutect2, varscan2
- FOLH1 | c.1397G>A p.C466Y | Missense Mutation (SNP) | VAF 59/214 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- FOSL2 | c.131G>A p.G44D | Missense Mutation (SNP) | VAF 81/261 reads (31%) | SIFT tolerated (0.26); PolyPhen benign (0.081); called by muse, mutect2, varscan2
- FOXO6 | c.932A>G p.H311R | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT tolerated (0.05); called by mutect2, varscan2
- FREM2 | c.8613_8614del p.W2872Vfs*3 | Frame Shift Del (DEL) | VAF 102/515 reads (20%) | called by pindel, varscan2
- FREM3 | c.5284_5287del p.K1762* | Frame Shift Del (DEL) | VAF 49/160 reads (31%) | called by mutect2, pindel
- FREM3 | c.839G>T p.G280V | Missense Mutation (SNP) | VAF 31/152 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- FRMD4A | c.1522C>T p.Q508* | Nonsense Mutation (SNP) | VAF 105/413 reads (25%) | called by muse, mutect2, varscan2
- FUT10 | c.484C>T p.P162S | Missense Mutation (SNP) | VAF 75/290 reads (26%) | SIFT tolerated (0.11); PolyPhen benign (0.111); called by muse, mutect2, varscan2
- FXYD1 | c.26T>C p.V9A | Missense Mutation (SNP) | VAF 30/134 reads (22%) | SIFT tolerated (0.08); PolyPhen benign (0); called by muse, mutect2, varscan2
- FYB1 | c.972del p.P325Hfs*44 | Frame Shift Del (DEL) | VAF 48/185 reads (26%) | called by mutect2, pindel, varscan2
- FZD8 | c.845G>A p.G282D | Missense Mutation (SNP) | VAF 29/89 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- GAK | c.3329C>G p.A1110G | Missense Mutation (SNP) | VAF 12/146 reads (8%) | SIFT tolerated (0.22); PolyPhen benign (0.206); called by muse, mutect2
- GCNT4 | c.673A>G p.N225D | Missense Mutation (SNP) | VAF 9/228 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- GEMIN5 | c.3164C>T p.A1055V | Missense Mutation (SNP) | VAF 101/342 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.531); called by muse, mutect2, varscan2
- GIGYF2 | c.3797del p.K1266Sfs*12 | Frame Shift Del (DEL) | VAF 138/505 reads (27%) | called by mutect2, pindel, varscan2
- GLI2 | c.3706del p.Q1236Sfs*2 (on ENST00000361492 / NM_001374353.1; = p.Q1253Sfs*2 on NM_005270.5 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 11/143 reads (8%) | called by mutect2, pindel
- GLP2R | c.942_945del p.F314Lfs*33 | Frame Shift Del (DEL) | VAF 36/193 reads (19%) | called by mutect2, pindel, varscan2
- GPR139 | c.761G>A p.G254E | Missense Mutation (SNP) | VAF 49/182 reads (27%) | SIFT tolerated (0.15); PolyPhen benign (0.1); called by muse, mutect2, varscan2
- GPR179 | c.3926A>G p.K1309R (on ENST00000621958; = p.K1308R on NM_001004334.4) | Missense Mutation (SNP) | VAF 20/288 reads (7%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.536); called by muse, mutect2
- GPRASP2 | c.263C>T p.T88M | Missense Mutation (SNP) | VAF 82/214 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- GPRC5B | c.793del p.D265Mfs*143 | Frame Shift Del (DEL) | VAF 104/363 reads (29%) | called by mutect2, pindel, varscan2
- GRIN3A | c.2884C>T p.R962* | Nonsense Mutation (SNP) | VAF 135/473 reads (29%) | called by muse, mutect2, varscan2
- GRIN3A | c.76G>A p.A26T | Missense Mutation (SNP) | VAF 138/455 reads (30%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.398); called by muse, mutect2, varscan2
- GSE1 | c.2708C>T p.A903V | Missense Mutation (SNP) | VAF 40/170 reads (24%) | SIFT tolerated (0.24); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- GSPT1 | c.159_161del p.E56del (on ENST00000420576 / NM_001130007.2; = p.E194del on NM_002094.4) | In Frame Del (DEL) | VAF 112/436 reads (26%) | called by pindel, varscan2
- GTF2IRD1 | c.1440dup p.G481Wfs*17 | Frame Shift Ins (INS) | VAF 43/173 reads (25%) | called by mutect2, pindel, varscan2
- GUSB | c.518A>T p.N173I | Missense Mutation (SNP) | VAF 71/308 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- HAPLN4 | c.542C>T p.A181V | Missense Mutation (SNP) | VAF 22/85 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- HDX | c.380A>C p.D127A | Missense Mutation (SNP) | VAF 37/103 reads (36%) | SIFT tolerated (0.34); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- HERC2 | c.11783_11784del p.E3928Afs*15 | Frame Shift Del (DEL) | VAF 55/228 reads (24%) | called by pindel, varscan2
- HLF | c.535C>T p.P179S | Missense Mutation (SNP) | VAF 77/331 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- HNRNPA3 | c.67del p.E23Rfs*12 | Frame Shift Del (DEL) | VAF 28/95 reads (29%) | called by mutect2, pindel
- HNRNPUL1 | c.2171del p.P724Qfs*191 | Frame Shift Del (DEL) | VAF 70/213 reads (33%) | called by mutect2, varscan2
- HOXB4 | c.745del p.R249Afs*20 | Frame Shift Del (DEL) | VAF 39/102 reads (38%) | called by mutect2, pindel, varscan2
- HOXD4 | c.170T>C p.F57S | Missense Mutation (SNP) | VAF 14/336 reads (4%) | SIFT tolerated (0.15); PolyPhen benign (0.068); called by muse, mutect2
- HSP90AB1 | c.859C>T p.P287S | Missense Mutation (SNP) | VAF 55/268 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- HUWE1 | c.443T>C p.I148T | Missense Mutation (SNP) | VAF 45/139 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- IGSF3 | c.2645C>T p.A882V (on ENST00000369486 / NM_001007237.3; = p.A902V on NM_001542.4) | Missense Mutation (SNP) | VAF 57/212 reads (27%) | SIFT tolerated (0.46); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- IL10RA | c.1147A>G p.T383A | Missense Mutation (SNP) | VAF 9/89 reads (10%) | SIFT tolerated (0.16); PolyPhen benign (0.112); called by muse, mutect2
- INHBB | c.776C>T p.A259V | Missense Mutation (SNP) | VAF 53/229 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.281); called by muse, mutect2, varscan2
- IQGAP2 | c.2133G>A p.M711I | Missense Mutation (SNP) | VAF 37/217 reads (17%) | SIFT tolerated (0.46); PolyPhen benign (0); called by muse, mutect2, varscan2
- IRF2BPL | c.2333G>A p.G778D | Missense Mutation (SNP) | VAF 15/56 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- IRS1 | c.1103del p.P368Rfs*95 | Frame Shift Del (DEL) | VAF 30/65 reads (46%) | called by mutect2, pindel, varscan2
- ITFG1 | c.1331-5C>T | Splice Region (SNP) | VAF 30/93 reads (32%) | called by muse, mutect2, varscan2
- ITGA7 | c.3248G>A p.W1083* (on ENST00000555728; = p.W1039* on NM_002206.3 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 128/551 reads (23%) | called by muse, mutect2, varscan2
882 further variants in this file (314 protein-altering or splice-affecting, 353 silent, 215 other) are not listed here.
